Somatic mutation profile of tumor specimen TCGA-55-1592-01A (aliquot TCGA-55-1592-01A-01D-0969-08) from TCGA case TCGA-55-1592, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IA.
Specimen TCGA-55-1592-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e4345630-2e05-4fa2-9009-164fa62c4c4f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-55-1592-11A (Solid Tissue Normal), aliquot TCGA-55-1592-11A-01D-0969-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8a0ad5f7-749a-487d-952a-603ec1a5de50

The open-access MAF lists 562 somatic variants for this specimen: 431 protein-altering or splice-affecting, 116 silent, 15 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 381, Silent 116, Nonsense Mutation 24, Intron 10, Splice Site 7, Frame Shift Del 7, Splice Region 5, In Frame Del 4, RNA 3, Frame Shift Ins 3, 5'Flank 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.730G>T p.G244C | Missense Mutation (SNP) | VAF 31/58 reads (53%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1057519989, CM144215, COSV52668392, COSV52676997, COSV52808251; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- ABCA8 | c.2685G>T p.Q895H | Missense Mutation (SNP) | VAF 25/114 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52197399, COSV52203326; called by muse, mutect2, varscan2
- ABCA9 | c.932G>A p.G311D | Missense Mutation (SNP) | VAF 21/82 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60626177; called by muse, mutect2, varscan2
- AC127029.3 | c.570C>A p.S190= | Splice Region (SNP) | VAF 116/261 reads (44%) | catalogued as COSV60111139; called by muse, mutect2, varscan2
- ACBD4 | c.518G>A p.R173K | Missense Mutation (SNP) | VAF 136/519 reads (26%) | SIFT tolerated (0.13); PolyPhen benign (0.024); catalogued as rs1214720668, COSV58852200; called by muse, mutect2, varscan2
- ACTN2 | c.494C>A p.T165N | Missense Mutation (SNP) | VAF 14/377 reads (4%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as COSV63975680; called by muse, mutect2
- ADAMTS16 | c.1069C>T p.H357Y | Missense Mutation (SNP) | VAF 101/270 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1193968598, COSV56992843; called by muse, mutect2, varscan2
- ADAMTS3 | c.3167C>T p.T1056I | Missense Mutation (SNP) | VAF 72/218 reads (33%) | SIFT tolerated (0.1); PolyPhen benign (0.073); catalogued as COSV54393841; called by muse, mutect2, varscan2
- ADAMTSL3 | c.2172G>T p.Q724H | Missense Mutation (SNP) | VAF 34/167 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54451861; called by muse, mutect2, varscan2
- ADAMTSL3 | c.3974-1G>T p.X1325_splice | Splice Site (SNP) | VAF 35/186 reads (19%) | catalogued as COSV54446136, COSV99718537; called by muse, mutect2, varscan2
- ADAMTSL3 | c.3974G>T p.G1325V | Missense Mutation (SNP) | VAF 35/185 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.844); catalogued as COSV99718546; called by muse, mutect2, varscan2
- ADGRB3 | c.4082T>A p.M1361K | Missense Mutation (SNP) | VAF 36/187 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.043); catalogued as COSV53247916; called by muse, mutect2, varscan2
- AFF3 | c.1601G>A p.R534K | Missense Mutation (SNP) | VAF 143/362 reads (40%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.999); catalogued as COSV100417076, COSV57856882; called by muse, mutect2, varscan2
- AGTR1 | c.604C>A p.L202M | Missense Mutation (SNP) | VAF 16/85 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV62558553; called by muse, mutect2, varscan2
- AJUBA | c.1186T>A p.F396I | Missense Mutation (SNP) | VAF 38/270 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.514); catalogued as COSV52985499; called by muse, mutect2, varscan2
- AKAP11 | c.3880G>C p.G1294R | Missense Mutation (SNP) | VAF 8/98 reads (8%) | SIFT tolerated (0.15); PolyPhen benign (0.316); catalogued as COSV50297567; called by muse, mutect2
- ALDH1B1 | c.1046G>T p.G349V | Missense Mutation (SNP) | VAF 63/99 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1387126303, COSV66620037; called by muse, mutect2, varscan2
- ALK | c.1693T>C p.S565P | Missense Mutation (SNP) | VAF 17/147 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as COSV66571859; called by muse, mutect2, varscan2
- ANKLE2 | c.220C>G p.L74V | Missense Mutation (SNP) | VAF 37/188 reads (20%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.785); catalogued as COSV61709846; called by muse, mutect2, varscan2
- AOC2 | c.130G>A p.A44T | Missense Mutation (SNP) | VAF 72/623 reads (12%) | SIFT tolerated (0.15); PolyPhen benign (0.003); catalogued as COSV53199493; called by muse, mutect2, varscan2
- ARHGAP11A | c.1522A>G p.T508A | Missense Mutation (SNP) | VAF 18/111 reads (16%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.609); catalogued as COSV64381125; called by muse, mutect2, varscan2
- ARHGEF6 | c.329C>T p.T110I | Missense Mutation (SNP) | VAF 21/109 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV51692095; called by muse, mutect2, varscan2
- ARMC3 | c.1718A>G p.Y573C | Missense Mutation (SNP) | VAF 107/204 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53062601; called by muse, varscan2
- ARSB | c.1190C>T p.P397L | Missense Mutation (SNP) | VAF 27/119 reads (23%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.807); catalogued as rs367922842, COSV53724927; called by muse, mutect2, varscan2
- ASAH2 | c.197G>T p.R66L | Missense Mutation (SNP) | VAF 36/109 reads (33%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0); catalogued as COSV61483626; called by muse, mutect2, varscan2
- ATF6B | c.898C>T p.P300S | Missense Mutation (SNP) | VAF 48/146 reads (33%) | SIFT tolerated (0.06); PolyPhen benign (0.006); catalogued as COSV64352039; called by muse, mutect2, varscan2
- ATG2B | c.3919G>T p.V1307F | Missense Mutation (SNP) | VAF 22/102 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.663); catalogued as COSV55890759; called by muse, mutect2, varscan2
- ATP1B4 | c.450G>T p.K150N (on ENST00000218008 / NM_001142447.3; = p.K146N on NM_012069.5) | Missense Mutation (SNP) | VAF 424/556 reads (76%) | SIFT tolerated (0.39); PolyPhen benign (0.018); catalogued as rs760016365, COSV54313163; called by muse, mutect2, varscan2
- ATRN | c.947C>A p.P316H | Missense Mutation (SNP) | VAF 64/195 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.76); catalogued as COSV53528927; called by muse, varscan2
- ATRNL1 | c.2113T>A p.Y705N | Missense Mutation (SNP) | VAF 23/71 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.057); catalogued as COSV61806197; called by muse, mutect2, varscan2
- BASP1 | c.673G>A p.V225M | Missense Mutation (SNP) | VAF 18/110 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV59471462; called by muse, mutect2, varscan2
- BHMT | c.1063C>A p.L355I | Missense Mutation (SNP) | VAF 117/253 reads (46%) | SIFT tolerated (0.07); PolyPhen benign (0.048); catalogued as COSV57154606; called by muse, mutect2, varscan2
- BMPER | c.785G>T p.R262M | Missense Mutation (SNP) | VAF 22/116 reads (19%) | SIFT deleterious (0.04); PolyPhen benign (0.073); catalogued as COSV51821252; called by muse, mutect2, varscan2
- BPIFB4 | c.1310A>T p.Q437L | Missense Mutation (SNP) | VAF 71/211 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.171); catalogued as COSV64951423; called by muse, mutect2, varscan2
- CALHM1 | c.262C>A p.R88S | Missense Mutation (SNP) | VAF 12/55 reads (22%) | SIFT tolerated (0.09); PolyPhen benign (0.04); catalogued as COSV61707712; called by muse, mutect2, varscan2
- CAPN11 | c.692G>A p.G231E | Missense Mutation (SNP) | VAF 76/271 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.874); catalogued as COSV67237981; called by muse, mutect2, varscan2
- CAPN7 | c.2072G>C p.R691P | Missense Mutation (SNP) | VAF 17/53 reads (32%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.988); catalogued as COSV53778148, COSV53778796, COSV99512580; called by muse, mutect2, varscan2
- CBLB | c.2731C>T p.R911C | Missense Mutation (SNP) | VAF 8/128 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.993); catalogued as rs990086709, COSV51428844; called by muse, mutect2
- CC2D2B | c.657T>C p.N219= | Splice Region (SNP) | VAF 15/122 reads (12%) | catalogued as COSV60358140; called by muse, mutect2, varscan2
- CCDC170 | c.888C>A p.S296R | Missense Mutation (SNP) | VAF 18/66 reads (27%) | SIFT tolerated (0.33); PolyPhen benign (0.019); catalogued as COSV53341823; called by muse, mutect2, varscan2
- CCSER1 | c.901G>T p.A301S | Missense Mutation (SNP) | VAF 70/261 reads (27%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.359); catalogued as COSV61438459; called by muse, mutect2, varscan2
- CDC25A | c.1100C>G p.S367C | Missense Mutation (SNP) | VAF 31/152 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.957); catalogued as COSV100207440, COSV56770914; called by muse, mutect2, varscan2
- CDC5L | c.541C>A p.R181S | Missense Mutation (SNP) | VAF 26/72 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV65176262; called by muse, varscan2
- CDH11 | c.2306A>G p.Y769C | Missense Mutation (SNP) | VAF 76/219 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.95); catalogued as COSV51764979, COSV51765076; called by muse, mutect2, varscan2
- CDHR1 | c.1205C>T p.P402L | Missense Mutation (SNP) | VAF 7/55 reads (13%) | SIFT tolerated (0.13); PolyPhen benign (0.037); catalogued as COSV60563159; called by muse, mutect2, varscan2
- CEP55 | c.427G>C p.E143Q | Missense Mutation (SNP) | VAF 24/136 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs1265810042, COSV65185231; called by muse, varscan2
- CFAP52 | c.1068C>G p.I356M | Missense Mutation (SNP) | VAF 5/99 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV55345605; called by muse, mutect2
- CFHR5 | c.1250G>T p.C417F | Missense Mutation (SNP) | VAF 20/81 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56822848; called by muse, mutect2, varscan2
- CIAO2A | c.250A>T p.T84S | Missense Mutation (SNP) | VAF 16/65 reads (25%) | SIFT tolerated (0.1); PolyPhen benign (0.001); catalogued as COSV55538631; called by muse, mutect2, varscan2
- CLEC7A | c.142G>A p.V48I | Missense Mutation (SNP) | VAF 5/10 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.482); catalogued as COSV53722604; called by muse, mutect2, varscan2
- CNGA2 | c.1046A>G p.E349G | Missense Mutation (SNP) | VAF 26/256 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV61704938; called by mutect2, varscan2
- COL15A1 | c.3295G>T p.G1099W | Missense Mutation (SNP) | VAF 64/115 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66645962; called by muse, mutect2, varscan2
- COL2A1 | c.2147A>G p.Q716R | Missense Mutation (SNP) | VAF 75/176 reads (43%) | SIFT tolerated (0.55); PolyPhen probably damaging (0.932); catalogued as rs1252045461, COSV61531460; called by muse, mutect2, varscan2
- COL6A6 | c.1964G>C p.G655A | Missense Mutation (SNP) | VAF 53/277 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.894); catalogued as COSV62027478; called by muse, mutect2, varscan2
- COMMD2 | c.74_75insT p.E26Rfs*30 | Frame Shift Ins (INS) | VAF 31/185 reads (17%) | catalogued as COSV101511898; called by mutect2, pindel, varscan2
- COX7A2L | c.268A>T p.T90S | Missense Mutation (SNP) | VAF 30/85 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.901); catalogued as COSV52243290; called by muse, mutect2, varscan2
- CPSF1 | c.2006T>C p.L669P | Missense Mutation (SNP) | VAF 24/141 reads (17%) | SIFT tolerated (0.06); PolyPhen benign (0.334); catalogued as COSV58233883; called by muse, mutect2, varscan2
- CR1L | c.651G>A p.W217* | Nonsense Mutation (SNP) | VAF 72/494 reads (15%) | catalogued as COSV54327175; called by muse, mutect2, varscan2
- CREB3L2 | c.975-2A>T p.X325_splice | Splice Site (SNP) | VAF 8/92 reads (9%) | catalogued as COSV57796229; called by muse, mutect2
- CSMD1 | c.8365C>A p.L2789M (on ENST00000520002; = p.L2788M on NM_033225.6) | Missense Mutation (SNP) | VAF 14/62 reads (23%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.996); catalogued as rs1201988082, COSV59334691; called by muse, mutect2, varscan2
- CSMD2 | c.148G>T p.A50S | Missense Mutation (SNP) | VAF 24/94 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV53920513; called by muse, varscan2
- CSMD3 | c.9840T>A p.S3280R (on ENST00000297405 / NM_001363185.1; = p.S3111R on NM_052900.3) | Missense Mutation (SNP) | VAF 36/106 reads (34%) | SIFT tolerated (0.27); PolyPhen benign (0.06); catalogued as COSV52202448, COSV52204664; called by muse, varscan2
- CUL2 | c.739G>T p.E247* | Nonsense Mutation (SNP) | VAF 7/67 reads (10%) | catalogued as COSV66079459; called by muse, mutect2
- CWF19L2 | c.2306A>C p.E769A | Missense Mutation (SNP) | VAF 31/111 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV56513890; called by muse, mutect2, varscan2
- CXCL9 | c.93T>A p.C31* | Nonsense Mutation (SNP) | VAF 84/261 reads (32%) | catalogued as COSV53579076; called by muse, mutect2, varscan2
- CYFIP1 | c.3461G>C p.G1154A | Missense Mutation (SNP) | VAF 24/106 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV57410655; called by muse, mutect2, varscan2
- CYP1A1 | c.842T>A p.I281N | Missense Mutation (SNP) | VAF 29/163 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV65697445; called by muse, mutect2, varscan2
- CYP1B1 | c.1564C>G p.L522V | Missense Mutation (SNP) | VAF 61/198 reads (31%) | SIFT tolerated (0.09); PolyPhen benign (0.073); catalogued as COSV52225999; called by muse, mutect2, varscan2
- CYP2A7 | c.386G>T p.R129L | Missense Mutation (SNP) | VAF 16/58 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.076); catalogued as rs1555785448, COSV52501710; called by muse, mutect2, varscan2
- CYP3A7 | c.825G>A p.M275I | Missense Mutation (SNP) | VAF 24/186 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.425); catalogued as COSV60481837; called by muse, mutect2, varscan2
- DACH2 | c.71G>T p.R24L | Missense Mutation (SNP) | VAF 8/16 reads (50%) | SIFT deleterious (0.01); PolyPhen benign (0.14); catalogued as COSV100914085, COSV64171805; called by muse, mutect2, varscan2
- DBX2 | c.793C>A p.L265I | Missense Mutation (SNP) | VAF 52/181 reads (29%) | SIFT tolerated (0.09); PolyPhen benign (0.035); catalogued as COSV60338030; called by muse, mutect2, varscan2
- DCAF12L1 | c.349T>C p.C117R | Missense Mutation (SNP) | VAF 31/116 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV64421720; called by muse, mutect2, varscan2
- DCDC1 | c.941G>T p.G314V | Missense Mutation (SNP) | VAF 25/89 reads (28%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.711); catalogued as COSV100663300, COSV60848797; called by muse, mutect2, varscan2
- DCDC1 | c.940G>T p.G314* | Nonsense Mutation (SNP) | VAF 25/93 reads (27%) | catalogued as COSV100663301; called by muse, mutect2, varscan2
- DCHS1 | c.862G>T p.G288W | Missense Mutation (SNP) | VAF 50/185 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55033797, COSV55037051; called by muse, mutect2, varscan2
- DCLK1 | c.134G>T p.R45L | Missense Mutation (SNP) | VAF 73/135 reads (54%) | SIFT deleterious (0.04); PolyPhen benign (0.124); catalogued as COSV55191105; called by muse, mutect2, varscan2
- DDB1 | c.2494G>A p.G832S | Missense Mutation (SNP) | VAF 30/169 reads (18%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); catalogued as COSV57103437; called by muse, mutect2, varscan2
- DDX20 | c.1760A>G p.Y587C | Missense Mutation (SNP) | VAF 88/262 reads (34%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as COSV63779535; called by muse, mutect2, varscan2
- DEFB112 | c.214G>A p.D72N | Missense Mutation (SNP) | VAF 27/140 reads (19%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.021); catalogued as rs267601067, COSV59182453; called by muse, varscan2
- DENND2A | c.971G>C p.R324T | Missense Mutation (SNP) | VAF 18/192 reads (9%) | SIFT deleterious (0.04); PolyPhen benign (0.266); catalogued as COSV52052611; called by muse, mutect2
- DEUP1 | c.902G>C p.G301A | Missense Mutation (SNP) | VAF 12/49 reads (24%) | SIFT tolerated (0.55); PolyPhen benign (0.242); catalogued as COSV53212959; called by muse, mutect2, varscan2
- DGKB | c.1177C>T p.Q393* | Nonsense Mutation (SNP) | VAF 11/33 reads (33%) | catalogued as COSV51790136; called by muse, mutect2
- DHX37 | c.2906G>T p.S969I | Missense Mutation (SNP) | VAF 176/311 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); catalogued as COSV58135470; called by muse, mutect2, varscan2
- DIRAS3 | c.308G>T p.R103L | Missense Mutation (SNP) | VAF 63/396 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); catalogued as COSV63970471, COSV63970813; called by muse, mutect2, varscan2
- DISP1 | c.3671C>G p.A1224G | Missense Mutation (SNP) | VAF 42/162 reads (26%) | SIFT tolerated, low confidence (0.35); PolyPhen benign (0.424); catalogued as COSV52660316; called by muse, mutect2, varscan2
- DISP3 | c.3874G>T p.A1292S | Missense Mutation (SNP) | VAF 39/116 reads (34%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.875); catalogued as rs865834710, COSV53829192, COSV53830869; called by muse, mutect2, varscan2
- DLG2 | c.2464C>G p.R822G | Missense Mutation (SNP) | VAF 19/129 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.958); catalogued as COSV54652274; called by muse, mutect2, varscan2
- DLX3 | c.216T>A p.N72K | Missense Mutation (SNP) | VAF 47/162 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.781); catalogued as COSV71547698; called by muse, mutect2, varscan2
- DNAH8 | c.8459G>T p.G2820V | Missense Mutation (SNP) | VAF 14/119 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV59452932; called by muse, mutect2, varscan2
- DPEP2 | c.295G>T p.V99F | Missense Mutation (SNP) | VAF 43/189 reads (23%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV52054813; called by muse, mutect2, varscan2
- DPM1 | c.421G>A p.D141N | Missense Mutation (SNP) | VAF 10/196 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); catalogued as COSV65373331; called by muse, mutect2
- DPP4 | c.1730G>C p.S577T | Missense Mutation (SNP) | VAF 12/262 reads (5%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.986); catalogued as COSV62107243; called by muse, mutect2
- DRC1 | c.1919G>T p.R640M | Missense Mutation (SNP) | VAF 15/92 reads (16%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.974); catalogued as COSV55505723; called by muse, mutect2, varscan2
- DSCAML1 | c.4455C>A p.S1485R (on ENST00000321322; = p.S1425R on NM_020693.4) | Missense Mutation (SNP) | VAF 55/99 reads (56%) | SIFT deleterious (0); PolyPhen possibly damaging (0.856); catalogued as COSV58392760, COSV58402749; called by muse, mutect2, varscan2
- DSG3 | c.2592T>A p.D864E | Missense Mutation (SNP) | VAF 28/147 reads (19%) | SIFT tolerated (0.24); PolyPhen benign (0.109); catalogued as COSV57126961; called by muse, mutect2, varscan2
- DSPP | c.865G>T p.D289Y | Missense Mutation (SNP) | VAF 18/76 reads (24%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.076); catalogued as COSV56811227, COSV99217697; called by muse, mutect2, varscan2
- DYTN | c.1564C>A p.L522M | Missense Mutation (SNP) | VAF 121/368 reads (33%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.641); catalogued as COSV71752261; called by muse, mutect2, varscan2
- EDNRB | c.663C>G p.C221W (on ENST00000377211 / NM_001201397.1; = p.C131W on NM_000115.5) | Missense Mutation (SNP) | VAF 76/138 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV57523605; called by muse, mutect2, varscan2
- EEF1A1 | c.644A>G p.K215R | Missense Mutation (SNP) | VAF 33/85 reads (39%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.794); catalogued as COSV58549891; called by muse, mutect2, varscan2
- EIF2AK3 | c.1540G>C p.D514H | Missense Mutation (SNP) | VAF 78/224 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100303909, COSV57548521; called by muse, mutect2, varscan2
- EMCN | c.535G>A p.A179T | Missense Mutation (SNP) | VAF 22/81 reads (27%) | SIFT tolerated (0.58); PolyPhen benign (0.303); catalogued as COSV56459799; called by muse, mutect2, varscan2
- EMILIN3 | c.1818C>A p.S606R | Missense Mutation (SNP) | VAF 69/210 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.829); catalogued as COSV60035614; called by muse, mutect2, varscan2
- ENPEP | c.1451C>T p.S484F | Missense Mutation (SNP) | VAF 26/86 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV54452308; called by muse, mutect2, varscan2
- EPB41L4B | c.2333A>G p.H778R | Missense Mutation (SNP) | VAF 36/58 reads (62%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0); catalogued as COSV65803446; called by muse, mutect2, varscan2
- EPS8L3 | c.1295A>G p.H432R | Missense Mutation (SNP) | VAF 136/474 reads (29%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as COSV62609675; called by muse, varscan2
- ERVW-1 | c.184T>A p.F62I | Missense Mutation (SNP) | VAF 70/309 reads (23%) | SIFT tolerated (0.19); PolyPhen benign (0.146); catalogued as COSV101423830; called by muse, mutect2, varscan2
- EXO1 | c.2285G>T p.R762I | Missense Mutation (SNP) | VAF 34/83 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.232); catalogued as COSV62217892; called by muse, mutect2, varscan2
- F2RL1 | c.491T>A p.L164H | Missense Mutation (SNP) | VAF 77/341 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56995878; called by muse, mutect2, varscan2
- FAM111B | c.312C>A p.S104R | Missense Mutation (SNP) | VAF 36/125 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as rs150852006, COSV59112197; called by muse, mutect2, varscan2
- FAM135B | c.2192G>T p.G731V | Missense Mutation (SNP) | VAF 31/91 reads (34%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.731); catalogued as COSV99423135; called by muse, mutect2, varscan2
- FAM135B | c.2191G>T p.G731* | Nonsense Mutation (SNP) | VAF 30/90 reads (33%) | catalogued as COSV99423142; called by muse, mutect2, varscan2
- FAM47C | c.2327C>A p.P776Q | Missense Mutation (SNP) | VAF 15/41 reads (37%) | SIFT tolerated (0.16); PolyPhen benign (0.125); catalogued as COSV63727224; called by muse, mutect2, varscan2
- FASTKD2 | c.913G>C p.E305Q | Missense Mutation (SNP) | VAF 17/65 reads (26%) | SIFT deleterious (0.05); PolyPhen benign (0.152); catalogued as COSV52698727; called by muse, mutect2, varscan2
- FAT1 | c.5936T>G p.F1979C | Missense Mutation (SNP) | VAF 88/371 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV71674627; called by muse, mutect2, varscan2
- FCRLB | c.34C>A p.P12T | Missense Mutation (SNP) | VAF 49/142 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.021); catalogued as COSV61059919; called by muse, varscan2
- FMN2 | c.4463T>C p.M1488T | Missense Mutation (SNP) | VAF 59/156 reads (38%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.685); catalogued as COSV60433485; called by muse, mutect2, varscan2
- FOXR1 | c.612-2A>G p.X204_splice | Splice Site (SNP) | VAF 90/215 reads (42%) | catalogued as COSV57652487; called by muse, mutect2, varscan2
- FRMPD3 | c.2603G>T p.R868L | Missense Mutation (SNP) | VAF 23/43 reads (53%) | SIFT deleterious (0); PolyPhen benign (0.108); catalogued as rs776539807, COSV99346194; ClinVar: benign; called by muse, mutect2, varscan2
- FSHB | c.245C>A p.P82H | Missense Mutation (SNP) | VAF 22/116 reads (19%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as rs1044572003, COSV54222200; called by muse, mutect2, varscan2
- GABRA3 | c.16A>T p.T6S | Missense Mutation (SNP) | VAF 38/151 reads (25%) | SIFT tolerated, low confidence (0.77); PolyPhen benign (0.006); catalogued as COSV64800133; called by muse, mutect2, varscan2
- GABRB3 | c.845C>A p.T282N | Missense Mutation (SNP) | VAF 35/152 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54668277; called by muse, mutect2, varscan2
- GAL3ST2 | c.362T>C p.F121S | Missense Mutation (SNP) | VAF 16/46 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51950505; called by muse, mutect2, varscan2
- GAL3ST2 | c.405C>G p.F135L | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT tolerated (0.06); PolyPhen benign (0.065); catalogued as COSV51950516; called by muse, mutect2, varscan2
- GALNT15 | c.1267G>T p.D423Y | Missense Mutation (SNP) | VAF 56/172 reads (33%) | SIFT tolerated (1); PolyPhen benign (0.034); catalogued as COSV60217706, COSV60218833; called by muse, mutect2, varscan2
- GCAT | c.1060G>T p.G354C | Missense Mutation (SNP) | VAF 19/147 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV50649232; called by muse, mutect2, varscan2
- GJA10 | c.796G>T p.V266L | Missense Mutation (SNP) | VAF 24/96 reads (25%) | SIFT tolerated (0.14); PolyPhen benign (0.028); catalogued as COSV65355321; called by muse, mutect2, varscan2
- GLB1L2 | c.1221C>G p.I407M | Missense Mutation (SNP) | VAF 68/459 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.364); catalogued as COSV60278693; called by muse, varscan2
- GPR1 | c.218C>A p.T73N | Missense Mutation (SNP) | VAF 17/416 reads (4%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.845); catalogued as COSV67976933; called by muse, mutect2
- GRIN3A | c.2731G>T p.V911F | Missense Mutation (SNP) | VAF 30/59 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs200636529, COSV62454748; called by muse, mutect2, varscan2
- GRM7 | c.1943C>T p.A648V | Missense Mutation (SNP) | VAF 54/296 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV63147164; called by muse, mutect2, varscan2
- H2AC12 | c.221A>T p.N74I | Missense Mutation (SNP) | VAF 37/138 reads (27%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.953); catalogued as COSV63617137; called by muse, mutect2, varscan2
- H2BC4 | c.331G>C p.A111P | Missense Mutation (SNP) | VAF 16/206 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.935); catalogued as COSV58416468; called by muse, mutect2
- HACD4 | c.387C>A p.Y129* | Nonsense Mutation (SNP) | VAF 11/42 reads (26%) | catalogued as COSV72136725; called by muse, mutect2, varscan2
- HAPLN3 | c.327C>G p.H109Q | Missense Mutation (SNP) | VAF 25/131 reads (19%) | SIFT tolerated (0.26); PolyPhen benign (0.021); catalogued as COSV62085357; called by muse, mutect2, varscan2
- HAS2 | c.561G>A p.W187* | Nonsense Mutation (SNP) | VAF 76/418 reads (18%) | catalogued as COSV58262646, COSV58264595; called by muse, mutect2, varscan2
- HDAC2 | c.304C>G p.P102A | Missense Mutation (SNP) | VAF 7/70 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.874); catalogued as COSV64038443; called by muse, mutect2, varscan2
- HDGFL1 | c.175T>A p.Y59N | Missense Mutation (SNP) | VAF 29/109 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV57752156; called by muse, mutect2, varscan2
- HECW2 | c.2418C>A p.D806E | Missense Mutation (SNP) | VAF 16/64 reads (25%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.995); catalogued as rs773894772, COSV53657659, COSV53662211; called by muse, varscan2
- HECW2 | c.86A>T p.Q29L | Missense Mutation (SNP) | VAF 51/204 reads (25%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.071); catalogued as COSV53662230; called by muse, mutect2, varscan2
- HEG1 | c.1028T>A p.L343Q | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.467); catalogued as COSV60762912; called by muse, mutect2, varscan2
- HERC4 | c.2006C>A p.A669E (on ENST00000395198 / NM_022079.3; = p.A661E on NM_015601.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 14/209 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53272224; called by muse, mutect2
- HIP1 | c.2943G>T p.M981I | Missense Mutation (SNP) | VAF 41/207 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.759); catalogued as COSV61187144; called by muse, mutect2, varscan2
- HIVEP2 | c.6453C>G p.Y2151* | Nonsense Mutation (SNP) | VAF 26/123 reads (21%) | catalogued as COSV50017336; called by muse, mutect2, varscan2
- HNRNPK | c.92A>G p.Q31R | Missense Mutation (SNP) | VAF 18/87 reads (21%) | SIFT tolerated (0.14); PolyPhen benign (0.42); catalogued as rs757328394, COSV57936593; called by muse, mutect2, varscan2
- HOXB1 | c.699G>T p.R233S | Missense Mutation (SNP) | VAF 53/375 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53317553, COSV53318655; called by muse, mutect2, varscan2
- HRG | c.1099C>T p.H367Y | Missense Mutation (SNP) | VAF 5/27 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.5); catalogued as COSV51646060; called by muse, mutect2, varscan2
- HSPA8 | c.564G>A p.K188= | Splice Region (SNP) | VAF 20/243 reads (8%) | catalogued as COSV57084291; called by muse, mutect2
- HSPA9 | c.151A>G p.I51V | Missense Mutation (SNP) | VAF 30/58 reads (52%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs138260125; called by muse, varscan2
- HTR1F | c.899G>A p.G300D | Missense Mutation (SNP) | VAF 7/52 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV60389968; called by muse, mutect2, varscan2
- HUWE1 | c.2179A>T p.S727C | Missense Mutation (SNP) | VAF 41/83 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV53348678; called by muse, mutect2, varscan2
- HVCN1 | c.209C>T p.A70V | Missense Mutation (SNP) | VAF 13/74 reads (18%) | SIFT tolerated (0.44); PolyPhen benign (0); catalogued as COSV54372513; called by muse, mutect2, varscan2
- IL10RA | c.1552C>A p.Q518K | Missense Mutation (SNP) | VAF 59/131 reads (45%) | SIFT tolerated (0.3); PolyPhen benign (0.038); catalogued as COSV57140978; called by muse, mutect2, varscan2
- IL16 | c.2284G>A p.D762N (on ENST00000302987 / NM_172217.5; = p.D61N on NM_004513.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 21/124 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.005); catalogued as COSV57264438; called by muse, mutect2, varscan2
- IL2 | c.392C>A p.T131K | Missense Mutation (SNP) | VAF 11/62 reads (18%) | SIFT tolerated (0.34); PolyPhen benign (0.317); catalogued as COSV56986190; called by muse, mutect2, varscan2
- INPP4A | c.2779C>T p.Q927* (on ENST00000074304 / NM_001134224.1; = p.Q888* on NM_001566.2 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 26/61 reads (43%) | catalogued as COSV50796616; called by muse, mutect2, varscan2
- INPP5A | c.178A>C p.N60H | Missense Mutation (SNP) | VAF 7/63 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV61249648; called by muse, mutect2
- INSRR | c.413C>A p.A138D | Missense Mutation (SNP) | VAF 29/75 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV63874364; called by muse, mutect2, varscan2
- INTS13 | c.1275C>G p.N425K | Missense Mutation (SNP) | VAF 14/442 reads (3%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.995); catalogued as COSV53903098; called by muse, mutect2
- IRX1 | c.1265C>T p.A422V | Missense Mutation (SNP) | VAF 21/51 reads (41%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as COSV57360045; called by muse, mutect2, varscan2
- IST1 | c.573A>T p.E191D (on ENST00000535424 / NM_001270976.1; = p.E178D on NM_014761.4) | Missense Mutation (SNP) | VAF 13/103 reads (13%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.715); catalogued as COSV61709911; called by muse, mutect2, varscan2
- ITGA2 | c.927A>G p.I309M | Missense Mutation (SNP) | VAF 24/186 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1443002281, COSV56860888; called by muse, mutect2, varscan2
- KCNA2 | c.59A>G p.Q20R | Missense Mutation (SNP) | VAF 124/422 reads (29%) | SIFT tolerated (0.27); PolyPhen benign (0.075); catalogued as COSV60370279; called by muse, varscan2
- KEL | c.1649T>C p.V550A | Missense Mutation (SNP) | VAF 30/112 reads (27%) | SIFT tolerated (0.05); PolyPhen benign (0.062); catalogued as COSV62335621; called by muse, mutect2, varscan2
- KHDC3L | c.73G>A p.G25S | Missense Mutation (SNP) | VAF 22/106 reads (21%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.99); catalogued as rs770321628, COSV64869277, COSV64869316; called by muse, mutect2, varscan2
- KIAA1109 | c.4826C>T p.P1609L | Missense Mutation (SNP) | VAF 14/110 reads (13%) | SIFT tolerated (0.18); PolyPhen benign (0.005); catalogued as COSV52677037; called by muse, mutect2, varscan2
- KIF21A | c.4425G>C p.R1475S (on ENST00000361418 / NM_001378440.1; = p.R1462S on NM_017641.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 10/151 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62772623; called by muse, mutect2
- KIF21A | c.3560C>T p.T1187I (on ENST00000361418 / NM_001378440.1; = p.T1174I on NM_017641.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 61/424 reads (14%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as COSV62772636; called by muse, mutect2, varscan2
- KIF24 | c.2396A>C p.Q799P | Missense Mutation (SNP) | VAF 72/244 reads (30%) | SIFT deleterious (0.03); PolyPhen benign (0.361); catalogued as COSV52659285; called by muse, mutect2, varscan2
- KLF10 | c.39G>C p.E13D | Missense Mutation (SNP) | VAF 7/200 reads (4%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.107); catalogued as COSV53435747; called by muse, mutect2
- KRTAP10-2 | c.705C>G p.C235W | Missense Mutation (SNP) | VAF 64/146 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV59966163; called by muse, mutect2, varscan2
- KRTAP5-11 | c.254C>T p.S85F | Missense Mutation (SNP) | VAF 45/173 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.072); catalogued as COSV59369737, COSV59371638; called by muse, mutect2, varscan2
- L1CAM | c.1481G>A p.R494H | Missense Mutation (SNP) | VAF 86/110 reads (78%) | SIFT tolerated (0.56); PolyPhen benign (0); catalogued as rs782038855, COSV62828473; called by muse, mutect2, varscan2
- L3MBTL4 | c.1615C>A p.Q539K | Missense Mutation (SNP) | VAF 14/140 reads (10%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV53125595; called by muse, mutect2
- LAMA5 | c.8003G>A p.R2668Q | Missense Mutation (SNP) | VAF 10/55 reads (18%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs967471014, COSV53361912; called by muse, mutect2, varscan2
- LAMB4 | c.1165C>T p.P389S | Missense Mutation (SNP) | VAF 39/92 reads (42%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV52714159; called by muse, mutect2, varscan2
- LAMC2 | c.518A>T p.Y173F | Missense Mutation (SNP) | VAF 52/139 reads (37%) | SIFT tolerated (0.93); PolyPhen benign (0.204); catalogued as COSV51456390; called by muse, mutect2, varscan2
- LDLRAD4 | c.616A>T p.R206W | Missense Mutation (SNP) | VAF 48/210 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63338486; called by muse, mutect2, varscan2
- LEF1 | c.157A>G p.I53V | Missense Mutation (SNP) | VAF 40/196 reads (20%) | SIFT tolerated (1); PolyPhen benign (0.124); catalogued as COSV54468396; called by muse, varscan2
- LGALS2 | c.232C>A p.P78T | Missense Mutation (SNP) | VAF 112/375 reads (30%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.579); catalogued as COSV50756811; called by muse, mutect2, varscan2
- LILRB2 | c.157C>A p.L53I | Missense Mutation (SNP) | VAF 159/300 reads (53%) | SIFT deleterious (0.04); PolyPhen benign (0.221); catalogued as COSV58745976; called by muse, mutect2, varscan2
- LIMCH1 | c.2826G>C p.Q942H | Missense Mutation (SNP) | VAF 28/105 reads (27%) | SIFT tolerated (0.13); PolyPhen benign (0.332); catalogued as COSV58286379; called by muse, mutect2, varscan2
- LIN28A | c.194C>T p.A65V | Missense Mutation (SNP) | VAF 54/182 reads (30%) | SIFT tolerated (0.09); PolyPhen benign (0.015); catalogued as rs759205887, COSV54262163; called by muse, mutect2, varscan2
- LIN9 | c.1348C>T p.P450S (on ENST00000366808 / NM_001270410.2; = p.P395S on NM_173083.3 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 14/159 reads (9%) | SIFT tolerated (0.36); PolyPhen benign (0.02); catalogued as COSV60245442; called by muse, mutect2
- LINGO2 | c.1135C>A p.Q379K | Missense Mutation (SNP) | VAF 33/62 reads (53%) | SIFT tolerated (0.11); PolyPhen benign (0.091); catalogued as rs1356863550, COSV58060045, COSV58060477; called by muse, mutect2, varscan2
- LIPC | c.241C>A p.L81M | Missense Mutation (SNP) | VAF 70/319 reads (22%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.878); catalogued as COSV54423445; called by muse, mutect2, varscan2
- LMAN1 | c.139G>C p.E47Q | Missense Mutation (SNP) | VAF 49/168 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); catalogued as COSV51827344; called by muse, mutect2, varscan2
- LPP | c.259A>T p.N87Y | Missense Mutation (SNP) | VAF 58/383 reads (15%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV57095370; called by muse, mutect2, varscan2
- LRBA | c.4461G>C p.K1487N | Missense Mutation (SNP) | VAF 24/70 reads (34%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); catalogued as COSV63956937; called by muse, varscan2
- LRIF1 | c.1190A>G p.Q397R | Missense Mutation (SNP) | VAF 72/476 reads (15%) | SIFT tolerated (0.08); PolyPhen benign (0.012); catalogued as COSV63897513; called by muse, varscan2
- LRRC37B | c.1405A>G p.K469E | Missense Mutation (SNP) | VAF 60/194 reads (31%) | SIFT tolerated (0.57); PolyPhen benign (0.018); catalogued as COSV58952783; called by muse, mutect2, varscan2
- LRRC8C | c.747G>T p.R249S | Missense Mutation (SNP) | VAF 56/170 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64998651; called by muse, mutect2, varscan2
- LRRCC1 | c.1750A>G p.K584E | Missense Mutation (SNP) | VAF 18/127 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.554); catalogued as rs750920479, COSV64483753; called by muse, mutect2, varscan2
- LRRTM4 | c.382A>T p.T128S | Missense Mutation (SNP) | VAF 26/100 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV69140499; called by muse, mutect2, varscan2
- LTBP2 | c.3584G>A p.S1195N | Missense Mutation (SNP) | VAF 23/104 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.893); catalogued as COSV56208952; called by muse, mutect2, varscan2
- MACF1 | c.2497G>C p.D833H | Missense Mutation (SNP) | VAF 19/221 reads (9%) | catalogued as COSV58378127; called by muse, mutect2
- MACF1 | c.4141A>G p.I1381V | Missense Mutation (SNP) | VAF 34/129 reads (26%) | catalogued as rs367571121; called by muse, mutect2, varscan2
- MADD | c.3383A>C p.E1128A | Missense Mutation (SNP) | VAF 18/129 reads (14%) | SIFT tolerated (0.14); PolyPhen benign (0.142); catalogued as COSV60625183; called by muse, mutect2, varscan2
- MAEL | c.524-2A>G p.X175_splice | Splice Site (SNP) | VAF 11/213 reads (5%) | catalogued as COSV63112477; called by muse, mutect2
- MAGEB3 | c.919T>G p.Y307D | Missense Mutation (SNP) | VAF 18/42 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100854680; called by muse, mutect2, varscan2
- MAGEB3 | c.920A>T p.Y307F | Missense Mutation (SNP) | VAF 18/45 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.882); catalogued as rs1468005064, COSV100854683; called by muse, mutect2, varscan2
- MAP3K9 | c.2970G>T p.E990D (on ENST00000554752 / NM_001284230.1; = p.E1004D on NM_033141.4) | Missense Mutation (SNP) | VAF 57/152 reads (38%) | SIFT tolerated (0.33); PolyPhen benign (0.005); catalogued as rs966033544, COSV67121645; called by muse, varscan2
- MAST3 | c.2284T>G p.C762G | Missense Mutation (SNP) | VAF 4/44 reads (9%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as COSV53221836; called by muse, mutect2
- MATN2 | c.1266G>T p.E422D | Missense Mutation (SNP) | VAF 7/134 reads (5%) | SIFT tolerated (0.88); PolyPhen benign (0.003); catalogued as COSV54712755; called by muse, mutect2
- MBD1 | c.1522G>T p.E508* (on ENST00000269468 / NM_001323950.1; = p.E452* on NM_015844.2 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 37/133 reads (28%) | catalogued as COSV53997648, COSV54002458; called by muse, mutect2, varscan2
- MCHR2 | c.271C>T p.H91Y | Missense Mutation (SNP) | VAF 36/189 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.174); catalogued as COSV56004049; called by muse, mutect2, varscan2
- ME2 | c.878C>T p.A293V | Missense Mutation (SNP) | VAF 33/141 reads (23%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.46); catalogued as COSV58423028, COSV58423573; called by muse, mutect2, varscan2
- METTL18 | c.893A>G p.N298S | Missense Mutation (SNP) | VAF 12/67 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as COSV53679598; called by muse, mutect2, varscan2
- MFSD8 | c.1346C>T p.P449L | Missense Mutation (SNP) | VAF 35/101 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs780779080, COSV56551417; called by muse, mutect2, varscan2
- MGAT4C | c.827T>C p.L276S | Missense Mutation (SNP) | VAF 25/77 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59833557; called by muse, mutect2, varscan2
- MIB2 | c.2323G>A p.D775N | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT tolerated (0.33); PolyPhen probably damaging (0.999); catalogued as rs755577709, COSV61542389; called by muse, mutect2, varscan2
- MKI67 | c.2638G>T p.E880* | Nonsense Mutation (SNP) | VAF 67/264 reads (25%) | catalogued as COSV64074889, COSV64077528; called by muse, mutect2, varscan2
- MLIP | c.693T>A p.D231E | Missense Mutation (SNP) | VAF 18/76 reads (24%) | SIFT tolerated (0.71); PolyPhen possibly damaging (0.693); catalogued as rs142613357; called by muse, mutect2, varscan2
- MMS22L | c.3624G>A p.W1208* | Nonsense Mutation (SNP) | VAF 15/80 reads (19%) | catalogued as COSV51521982; called by muse, mutect2, varscan2
- MPP4 | c.538G>T p.A180S | Missense Mutation (SNP) | VAF 5/32 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs764247427, COSV59628990; called by mutect2, varscan2
- MRPL17 | c.207C>G p.N69K | Missense Mutation (SNP) | VAF 23/83 reads (28%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.738); catalogued as COSV56618505; called by muse, mutect2, varscan2
- MS4A5 | c.214T>A p.L72M | Missense Mutation (SNP) | VAF 66/255 reads (26%) | SIFT tolerated (0.07); PolyPhen benign (0.167); catalogued as COSV55741178; called by muse, mutect2, varscan2
- MS4A7 | c.22A>G p.M8V | Missense Mutation (SNP) | VAF 59/170 reads (35%) | SIFT tolerated (0.06); PolyPhen benign (0.001); catalogued as COSV55730077; called by muse, mutect2, varscan2
- MSLNL | c.2087T>G p.L696R | Missense Mutation (SNP) | VAF 20/129 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.353); catalogued as COSV53503084; called by muse, mutect2, varscan2
- MSX1 | c.816C>A p.Y272* | Nonsense Mutation (SNP) | VAF 8/38 reads (21%) | catalogued as COSV66947420; called by muse, varscan2
- MUC5AC | c.14914G>T p.G4972W | Missense Mutation (SNP) | VAF 9/36 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100611421; called by muse, mutect2, varscan2
- MUC7 | c.429A>C p.E143D | Missense Mutation (SNP) | VAF 54/334 reads (16%) | SIFT tolerated (0.34); PolyPhen benign (0.023); catalogued as COSV59218681; called by muse, mutect2, varscan2
- MYH11 | c.383A>G p.Y128C | Missense Mutation (SNP) | VAF 81/256 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV55556057; called by muse, mutect2, varscan2
- MYH15 | c.1441G>T p.E481* | Nonsense Mutation (SNP) | VAF 6/72 reads (8%) | catalogued as COSV99843086; called by muse, mutect2
- MYH15 | c.489G>C p.K163N | Missense Mutation (SNP) | VAF 43/80 reads (54%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.964); catalogued as COSV56311837; called by muse, mutect2, varscan2
- MYH6 | c.5764C>A p.L1922I | Missense Mutation (SNP) | VAF 37/191 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.053); catalogued as COSV59306200; called by muse, mutect2, varscan2
- NARS2 | c.772A>G p.M258V | Missense Mutation (SNP) | VAF 61/152 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.444); catalogued as rs1316806206, COSV55252432; called by muse, mutect2, varscan2
- NCKAP1L | c.2730C>G p.I910M | Missense Mutation (SNP) | VAF 37/137 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV53207888; called by muse, mutect2, varscan2
- NCKAP5 | c.5292G>T p.M1764I | Missense Mutation (SNP) | VAF 26/129 reads (20%) | SIFT tolerated (0.91); PolyPhen benign (0); catalogued as COSV58449373; called by muse, varscan2
- NEGR1 | c.624T>A p.D208E | Missense Mutation (SNP) | VAF 23/156 reads (15%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.585); catalogued as COSV60849593; called by muse, mutect2, varscan2
- NEO1 | c.1365C>G p.I455M | Missense Mutation (SNP) | VAF 56/258 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); catalogued as COSV56068162, COSV56072853; called by muse, mutect2, varscan2
- NF1 | c.5645G>A p.C1882Y (on ENST00000358273 / NM_001042492.3; = p.C1861Y on NM_000267.3) | Missense Mutation (SNP) | VAF 53/140 reads (38%) | SIFT tolerated (0.52); PolyPhen benign (0.127); catalogued as COSV62195751, COSV62225413; called by muse, mutect2, varscan2
- NFATC3 | c.3032G>A p.S1011N | Missense Mutation (SNP) | VAF 146/359 reads (41%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV60474748; called by muse, mutect2, varscan2
- NFYC | c.1357C>T p.P453S (on ENST00000308733 / NM_001308114.1; = p.P330S on NM_014223.5) | Missense Mutation (SNP) | VAF 22/146 reads (15%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.265); catalogued as COSV58127593; called by muse, mutect2, varscan2
- NLRP8 | c.2956C>A p.L986M | Missense Mutation (SNP) | VAF 102/203 reads (50%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.98); catalogued as COSV52582822; called by muse, mutect2, varscan2
- NMBR | c.835T>A p.W279R | Missense Mutation (SNP) | VAF 39/101 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV57801590; called by muse, mutect2, varscan2
- NMS | c.259G>A p.G87R | Missense Mutation (SNP) | VAF 21/94 reads (22%) | SIFT tolerated (0.19); PolyPhen benign (0.012); catalogued as COSV65258778; called by muse, mutect2, varscan2
- NPAP1 | c.511G>C p.G171R | Missense Mutation (SNP) | VAF 18/111 reads (16%) | SIFT tolerated (0.08); PolyPhen benign (0.314); catalogued as COSV61507839; called by muse, mutect2, varscan2
- NPAT | c.2809C>G p.P937A | Missense Mutation (SNP) | VAF 115/240 reads (48%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.999); catalogued as rs751161125, COSV53718641; called by muse, mutect2, varscan2
- NRDC | c.916A>G p.M306V | Missense Mutation (SNP) | VAF 22/72 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.801); catalogued as rs757688705, COSV61405055; called by muse, varscan2
- NRXN3 | c.1750T>C p.Y584H (on ENST00000557594 / NM_001272020.2; = p.Y1008H on NM_004796.6) | Missense Mutation (SNP) | VAF 18/81 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV55332062; called by muse, mutect2, varscan2
- NSF | c.1408G>A p.A470T | Missense Mutation (SNP) | VAF 20/174 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.147); catalogued as COSV56575142; called by muse, mutect2, varscan2
- NTRK3 | c.1071G>T p.E357D | Missense Mutation (SNP) | VAF 28/178 reads (16%) | SIFT tolerated (0.63); PolyPhen benign (0.006); catalogued as COSV58125802; called by muse, varscan2
- NUDT5 | c.616C>A p.H206N | Missense Mutation (SNP) | VAF 110/234 reads (47%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.462); catalogued as COSV53652757; called by mutect2, varscan2
- NUGGC | c.1655T>C p.V552A | Missense Mutation (SNP) | VAF 10/136 reads (7%) | SIFT tolerated (0.06); PolyPhen benign (0.031); catalogued as COSV58435719; called by muse, mutect2
- NUMB | c.1360C>T p.Q454* (on ENST00000355058; = p.Q443* on NM_003744.5) | Nonsense Mutation (SNP) | VAF 17/74 reads (23%) | catalogued as COSV53719116; called by muse, mutect2, varscan2
- NXPE4 | c.690C>G p.C230W | Missense Mutation (SNP) | VAF 25/260 reads (10%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV64943895; called by muse, mutect2
- OBSCN | c.14789G>T p.R4930L | Missense Mutation (SNP) | VAF 32/73 reads (44%) | SIFT tolerated (0.16); PolyPhen benign (0.327); catalogued as rs200664730, COSV52753743, COSV52783197; called by muse, mutect2, varscan2
- OLFM3 | c.722G>T p.W241L (on ENST00000338858 / NM_001288821.1; = p.W221L on NM_058170.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 52/224 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV58799542; called by muse, mutect2, varscan2
- OR10A3 | c.16C>T p.Q6* | Nonsense Mutation (SNP) | VAF 46/134 reads (34%) | catalogued as COSV62459619; called by muse, mutect2, varscan2
- OR10G4 | c.869G>A p.R290K | Missense Mutation (SNP) | VAF 90/206 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV57977094, COSV57977963; called by muse, mutect2, varscan2
- OR10T2 | c.404T>G p.L135R | Missense Mutation (SNP) | VAF 51/258 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.602); catalogued as COSV57781688, COSV57783958; called by muse, mutect2, varscan2
- OR11A1 | c.520C>T p.H174Y | Missense Mutation (SNP) | VAF 28/98 reads (29%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as COSV65821099; called by muse, mutect2, varscan2
- OR1M1 | c.47G>T p.G16V | Missense Mutation (SNP) | VAF 29/65 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV70036981; called by muse, mutect2, varscan2
- OR2A14 | c.805C>A p.Q269K | Missense Mutation (SNP) | VAF 103/441 reads (23%) | SIFT tolerated (0.09); PolyPhen benign (0.029); catalogued as COSV68718268; called by muse, mutect2, varscan2
- OR2G2 | c.34C>G p.L12V | Missense Mutation (SNP) | VAF 110/249 reads (44%) | SIFT tolerated (0.52); PolyPhen benign (0.021); catalogued as COSV60740787; called by muse, mutect2, varscan2
- OR52B2 | c.605T>C p.F202S | Missense Mutation (SNP) | VAF 12/67 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV73209417; called by muse, varscan2
- OR56A4 | c.261C>A p.S87R | Missense Mutation (SNP) | VAF 33/120 reads (28%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.805); catalogued as COSV58110470; called by muse, mutect2, varscan2
- OR5A2 | c.295G>C p.A99P | Missense Mutation (SNP) | VAF 46/124 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.968); catalogued as COSV57391203; called by muse, mutect2, varscan2
- OR6A2 | c.454G>T p.G152C | Missense Mutation (SNP) | VAF 32/111 reads (29%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.959); catalogued as COSV60265126; called by muse, mutect2, varscan2
- OR7A10 | c.499C>G p.P167A | Missense Mutation (SNP) | VAF 37/94 reads (39%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.005); catalogued as COSV50166447; called by muse, mutect2, varscan2
- OR7C2 | c.76C>T p.L26F | Missense Mutation (SNP) | VAF 67/135 reads (50%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.02); catalogued as COSV50180923; called by muse, mutect2, varscan2
- OR8K5 | c.280T>A p.Y94N | Missense Mutation (SNP) | VAF 36/162 reads (22%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.494); catalogued as COSV57889381; called by muse, mutect2, varscan2
- OSBPL8 | c.800C>T p.S267F | Missense Mutation (SNP) | VAF 16/89 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.923); catalogued as COSV53883957; called by muse, mutect2, varscan2
- OTX2 | c.646G>A p.G216R (on ENST00000408990 / NM_172337.3; = p.G224R on NM_021728.4) | Missense Mutation (SNP) | VAF 28/148 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.917); catalogued as COSV59766395; called by muse, mutect2, varscan2
- P2RY10 | c.830G>C p.C277S | Missense Mutation (SNP) | VAF 76/142 reads (54%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as COSV50681961; called by muse, mutect2, varscan2
- PACRG | c.353A>C p.E118A | Missense Mutation (SNP) | VAF 24/137 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV61306976; called by muse, mutect2, varscan2
- PANK4 | c.2252C>G p.A751G | Missense Mutation (SNP) | VAF 11/26 reads (42%) | SIFT tolerated (0.12); PolyPhen benign (0.099); catalogued as COSV53944366; called by muse, mutect2, varscan2
- PAPPA2 | c.1600G>T p.D534Y | Missense Mutation (SNP) | VAF 55/138 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV62779713; called by muse, mutect2, varscan2
- PCDH11Y | c.409C>G p.H137D (on ENST00000400457 / NM_032973.2; = p.H126D on NM_032971.3) | Missense Mutation (SNP) | VAF 103/173 reads (60%) | SIFT tolerated (0.23); PolyPhen benign (0.04); catalogued as COSV53082882; called by muse, mutect2, varscan2
- PCDH15 | c.4006G>T p.D1336Y | Missense Mutation (SNP) | VAF 30/99 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV57304285, COSV57327137; called by muse, mutect2, varscan2
- PCDHB3 | c.1302G>C p.K434N | Missense Mutation (SNP) | VAF 42/146 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.003); catalogued as COSV50580145; called by muse, mutect2, varscan2
- PCDHGA4 | c.1502C>T p.S501F | Missense Mutation (SNP) | VAF 42/166 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.961); catalogued as COSV53964364; called by muse, mutect2, varscan2
- PCNT | c.2672A>G p.Q891R | Missense Mutation (SNP) | VAF 12/106 reads (11%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV64029292; called by muse, mutect2
- PEX11A | c.366G>C p.R122S | Missense Mutation (SNP) | VAF 22/216 reads (10%) | SIFT tolerated (0.27); PolyPhen benign (0.084); catalogued as COSV55583991; called by muse, mutect2, varscan2
- PGLYRP2 | c.1127T>C p.F376S | Missense Mutation (SNP) | VAF 128/295 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV52994621; called by muse, mutect2, varscan2
- PHACTR3 | c.119-1G>A p.X40_splice | Splice Site (SNP) | VAF 111/347 reads (32%) | catalogued as COSV63029123; called by muse, mutect2, varscan2
- PIGO | c.1574T>G p.F525C | Missense Mutation (SNP) | VAF 74/120 reads (62%) | SIFT deleterious (0.03); PolyPhen benign (0.018); catalogued as COSV53053937; called by muse, mutect2, varscan2
- PIK3CB | c.2975T>C p.I992T | Missense Mutation (SNP) | VAF 13/56 reads (23%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.641); catalogued as COSV56686983; called by muse, mutect2, varscan2
- PIKFYVE | c.355G>T p.G119C | Missense Mutation (SNP) | VAF 49/179 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.781); catalogued as COSV52242858; called by muse, mutect2, varscan2
- PIWIL4 | c.919A>G p.N307D | Missense Mutation (SNP) | VAF 20/100 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV54409845; called by muse, varscan2
- PKHD1L1 | c.5195C>A p.P1732H | Missense Mutation (SNP) | VAF 154/372 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.95); catalogued as COSV65744988; called by mutect2, varscan2
- PKHD1L1 | c.10219T>A p.W3407R | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV65741975, COSV65744992; called by muse, mutect2, varscan2
- PLA2G2A | c.187T>A p.C63S | Missense Mutation (SNP) | VAF 26/88 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64287180; called by muse, mutect2, varscan2
- PLAT | c.173G>C p.R58P | Missense Mutation (SNP) | VAF 122/692 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54276168, COSV54277811; called by muse, mutect2, varscan2
- PLEKHO2 | c.1072G>T p.A358S | Missense Mutation (SNP) | VAF 32/115 reads (28%) | SIFT tolerated (0.38); PolyPhen benign (0.025); catalogued as COSV60262240; called by muse, mutect2, varscan2
- PLPPR5 | c.19G>A p.A7T | Missense Mutation (SNP) | VAF 45/115 reads (39%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0); catalogued as COSV54174193; called by muse, mutect2, varscan2
- PNCK | c.157G>T p.G53C (on ENST00000340888 / NM_001366975.1; = p.G136C on NM_001039582.3) | Missense Mutation (SNP) | VAF 29/129 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.979); catalogued as COSV61744176; called by muse, mutect2, varscan2
- POLD1 | c.790A>G p.N264D | Missense Mutation (SNP) | VAF 16/28 reads (57%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.735); catalogued as COSV70955529; called by muse, mutect2, varscan2
- POU6F2 | c.191G>C p.G64A | Missense Mutation (SNP) | VAF 14/66 reads (21%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.091); catalogued as COSV68874743; called by muse, mutect2, varscan2
- PPP1R13B | c.241C>T p.R81* | Nonsense Mutation (SNP) | VAF 24/108 reads (22%) | catalogued as rs749124281, COSV52452574; called by muse, mutect2, varscan2
- PPP2R5E | c.355G>C p.V119L | Missense Mutation (SNP) | VAF 7/99 reads (7%) | SIFT deleterious (0.04); PolyPhen benign (0.02); catalogued as COSV61742334; called by muse, mutect2
- PPY | c.80C>T p.A27V | Missense Mutation (SNP) | VAF 14/89 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0.031); catalogued as rs1369951004, COSV56823564; called by muse, mutect2, varscan2
- PRELP | c.601G>T p.D201Y | Missense Mutation (SNP) | VAF 32/377 reads (8%) | SIFT tolerated (0.12); PolyPhen probably damaging (1); catalogued as COSV58116201; called by muse, mutect2
- PRKCA | c.1875C>A p.N625K | Missense Mutation (SNP) | VAF 36/178 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV68951571; called by muse, mutect2, varscan2
- PRPF39 | c.719A>G p.Y240C | Missense Mutation (SNP) | VAF 102/340 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63276980; called by muse, mutect2, varscan2
- PTPN4 | c.2446A>G p.I816V | Missense Mutation (SNP) | VAF 94/207 reads (45%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1287968345, COSV55297118, COSV55302838; called by muse, mutect2, varscan2
- PTPRD | c.2774T>A p.L925H | Missense Mutation (SNP) | VAF 25/96 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.213); catalogued as COSV61925667, COSV61968854; called by muse, mutect2, varscan2
- PTPRR | c.790G>T p.E264* | Nonsense Mutation (SNP) | VAF 7/59 reads (12%) | catalogued as COSV51724852, COSV51735081; called by muse, mutect2
- PXDNL | c.1475G>A p.S492N | Missense Mutation (SNP) | VAF 60/294 reads (20%) | SIFT tolerated (1); PolyPhen benign (0.025); catalogued as COSV62489628; called by muse, mutect2, varscan2
- PZP | c.1536G>T p.E512D | Missense Mutation (SNP) | VAF 19/62 reads (31%) | SIFT tolerated (0.24); PolyPhen benign (0.012); catalogued as COSV54362585; called by muse, mutect2, varscan2
- RABGAP1 | c.1669A>T p.K557* | Nonsense Mutation (SNP) | VAF 51/109 reads (47%) | catalogued as COSV65392575, COSV65393790; called by muse, mutect2, varscan2
- RELN | c.7931G>A p.R2644K | Missense Mutation (SNP) | VAF 14/85 reads (16%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as COSV59008013; called by muse, mutect2, varscan2
- RFTN2 | c.1046T>C p.I349T | Missense Mutation (SNP) | VAF 23/107 reads (21%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); catalogued as rs1052148115, COSV54389184; called by muse, mutect2, varscan2
- RGL1 | c.1802C>T p.S601F (on ENST00000360851 / NM_001297672.2; = p.S636F on NM_015149.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 62/285 reads (22%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.99); catalogued as COSV58980409; called by muse, mutect2, varscan2
- RGS1 | c.373G>A p.E125K | Missense Mutation (SNP) | VAF 60/279 reads (22%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100817456, COSV66506528; called by muse, varscan2
- RGS1 | c.374A>G p.E125G | Missense Mutation (SNP) | VAF 60/269 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.015); catalogued as COSV100817461; called by mutect2, varscan2
- RGS5 | c.35G>T p.C12F | Missense Mutation (SNP) | VAF 17/69 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.007); catalogued as COSV58352887, COSV58353328; called by muse, mutect2, varscan2
- RIMS2 | c.1879A>C p.S627R (on ENST00000666250 / NM_001348490.2; = p.S435R on NM_014677.5 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 8/126 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51651922; called by muse, mutect2
- RIOX1 | c.1602A>T p.E534D | Missense Mutation (SNP) | VAF 16/82 reads (20%) | SIFT tolerated (0.26); PolyPhen benign (0.012); catalogued as COSV58374133; called by muse, mutect2, varscan2
- ROBO2 | c.1108G>T p.V370L | Missense Mutation (SNP) | VAF 55/121 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59915415; called by muse, mutect2, varscan2
- RTN4 | c.2090T>C p.I697T | Missense Mutation (SNP) | VAF 58/172 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.878); catalogued as COSV58268698; called by muse, mutect2, varscan2
- RTN4 | c.1519G>A p.E507K | Missense Mutation (SNP) | VAF 35/195 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.656); catalogued as COSV58268714; called by muse, mutect2, varscan2
- RTN4IP1 | c.928C>T p.R310* | Nonsense Mutation (SNP) | VAF 41/118 reads (35%) | catalogued as rs536455406, COSV64805564; called by muse, mutect2, varscan2
- RYR2 | c.13101G>T p.K4367N | Missense Mutation (SNP) | VAF 47/114 reads (41%) | SIFT tolerated (0.22); PolyPhen benign (0.042); catalogued as COSV100769803; called by muse, varscan2
- RYR2 | c.13102G>T p.E4368* | Nonsense Mutation (SNP) | VAF 48/112 reads (43%) | catalogued as COSV100769804; called by muse, varscan2
- SAT1 | c.134G>A p.G45D | Missense Mutation (SNP) | VAF 35/64 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV63380723; called by muse, mutect2, varscan2
- SCN2A | c.2797C>A p.L933M | Missense Mutation (SNP) | VAF 71/294 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51844322; called by muse, mutect2, varscan2
- SCN9A | c.100G>C p.E34Q | Missense Mutation (SNP) | VAF 44/235 reads (19%) | SIFT tolerated (0.25); PolyPhen benign (0.017); catalogued as COSV57612674, COSV57623553; called by muse, mutect2, varscan2
- SEC62 | c.78G>T p.K26N | Missense Mutation (SNP) | VAF 38/115 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV61261396; called by muse, mutect2, varscan2
- SERBP1 | c.1186C>G p.P396A (on ENST00000370995 / NM_001018067.2; = p.P375A on NM_015640.4) | Missense Mutation (SNP) | VAF 6/56 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.234); catalogued as COSV63413627; called by muse, mutect2
- SH3BP5L | c.587G>T p.R196L | Missense Mutation (SNP) | VAF 25/58 reads (43%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.859); catalogued as COSV63539378; called by muse, mutect2
- SI | c.4810G>A p.G1604S | Missense Mutation (SNP) | VAF 17/99 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52282913; called by muse, mutect2, varscan2
- SIM1 | c.1584G>T p.W528C | Missense Mutation (SNP) | VAF 23/124 reads (19%) | SIFT deleterious, low confidence (0.05); PolyPhen probably damaging (0.956); catalogued as COSV53493113; called by muse, mutect2, varscan2
- SLAMF9 | c.122C>A p.P41H | Missense Mutation (SNP) | VAF 76/228 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.865); catalogued as COSV63636793; called by muse, mutect2, varscan2
- SLC10A2 | c.654C>A p.S218R | Missense Mutation (SNP) | VAF 66/131 reads (50%) | SIFT deleterious (0.01); PolyPhen benign (0.049); catalogued as COSV55359663; called by muse, mutect2, varscan2
- SLC12A5 | c.1204C>A p.L402M (on ENST00000454036 / NM_001134771.2; = p.L379M on NM_020708.5) | Missense Mutation (SNP) | VAF 70/667 reads (10%) | SIFT tolerated (0.15); PolyPhen benign (0.243); catalogued as COSV54794865; called by muse, mutect2, varscan2
- SLC1A2 | c.476A>G p.N159S | Missense Mutation (SNP) | VAF 50/475 reads (11%) | SIFT tolerated (0.75); PolyPhen benign (0.065); catalogued as COSV53522240; called by muse, mutect2, varscan2
- SLC26A5 | c.1989T>A p.I663= | Splice Region (SNP) | VAF 29/137 reads (21%) | catalogued as COSV59702550; called by muse, mutect2, varscan2
- SLC35E3 | c.80G>T p.C27F | Missense Mutation (SNP) | VAF 27/84 reads (32%) | SIFT tolerated (0.09); PolyPhen benign (0.057); catalogued as COSV57495303; called by muse, mutect2, varscan2
- SLC4A7 | c.257C>G p.S86C | Missense Mutation (SNP) | VAF 17/149 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.41); catalogued as COSV55398207; called by muse, mutect2, varscan2
- SLC5A8 | c.1124C>T p.S375L | Missense Mutation (SNP) | VAF 16/85 reads (19%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.509); catalogued as rs773903392, COSV73310535; called by muse, mutect2, varscan2
- SLC6A16 | c.163C>T p.R55W | Missense Mutation (SNP) | VAF 9/71 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.036); catalogued as rs750477215, COSV60028283; called by muse, mutect2, varscan2
- SLC7A14 | c.543G>T p.G181= | Splice Region (SNP) | VAF 22/88 reads (25%) | catalogued as COSV51582545; called by muse, mutect2, varscan2
- SLC9B2 | c.1370G>T p.W457L | Missense Mutation (SNP) | VAF 16/70 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60019818; called by muse, mutect2, varscan2
- SLITRK2 | c.2071C>A p.P691T | Missense Mutation (SNP) | VAF 111/155 reads (72%) | SIFT deleterious (0.01); PolyPhen benign (0.376); catalogued as rs782664493, COSV59426040; called by muse, mutect2, varscan2
- SMAP1 | c.739G>T p.G247* (on ENST00000370455 / NM_001044305.3; = p.G220* on NM_021940.5) | Nonsense Mutation (SNP) | VAF 10/336 reads (3%) | catalogued as COSV57640644; called by muse, mutect2
- SMAP1 | c.740G>T p.G247V (on ENST00000370455 / NM_001044305.3; = p.G220V on NM_021940.5) | Missense Mutation (SNP) | VAF 10/336 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100016884, COSV57646309; called by muse, mutect2
- SPANXN2 | c.437G>A p.G146E | Missense Mutation (SNP) | VAF 120/1186 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.017); catalogued as COSV100979825, COSV65127756; called by muse, varscan2
- SPART | c.16C>G p.Q6E | Missense Mutation (SNP) | VAF 54/116 reads (47%) | SIFT tolerated (0.96); PolyPhen benign (0); catalogued as COSV62085784; called by muse, mutect2, varscan2
- SPINK7 | c.89T>A p.V30E | Missense Mutation (SNP) | VAF 128/256 reads (50%) | SIFT tolerated (0.09); PolyPhen benign (0.026); catalogued as COSV51001697; called by muse, mutect2, varscan2
- SSTR5 | c.490T>A p.W164R | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53512415; called by mutect2, varscan2
- ST14 | c.134A>G p.K45R | Missense Mutation (SNP) | VAF 48/109 reads (44%) | SIFT tolerated (0.12); PolyPhen benign (0.038); catalogued as COSV53833912; called by muse, mutect2, varscan2
- ST6GAL2 | c.223G>C p.D75H | Missense Mutation (SNP) | VAF 15/76 reads (20%) | PolyPhen benign (0.358); catalogued as COSV64528994; called by muse, mutect2, varscan2
- STAB2 | c.3851G>A p.C1284Y | Missense Mutation (SNP) | VAF 18/60 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV66340548; called by muse, mutect2, varscan2
- STK32C | c.271G>T p.D91Y | Missense Mutation (SNP) | VAF 24/89 reads (27%) | SIFT tolerated (0.21); PolyPhen benign (0.167); catalogued as rs142282211; called by muse, mutect2, varscan2
- SULT1B1 | c.876C>G p.F292L | Missense Mutation (SNP) | VAF 10/156 reads (6%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.825); catalogued as COSV60208000; called by muse, mutect2
- SURF4 | c.733G>T p.V245L | Missense Mutation (SNP) | VAF 15/71 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.511); catalogued as COSV64332398; called by muse, mutect2, varscan2
- TAF3 | c.2715G>C p.M905I | Missense Mutation (SNP) | VAF 17/66 reads (26%) | SIFT tolerated (0.14); PolyPhen benign (0.085); catalogued as COSV60207384; called by muse, mutect2, varscan2
- TBX18 | c.1799C>G p.S600C | Missense Mutation (SNP) | VAF 36/99 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.99); catalogued as COSV63736157, COSV63737111; called by muse, mutect2, varscan2
- TCF12 | c.928G>A p.A310T | Missense Mutation (SNP) | VAF 39/106 reads (37%) | SIFT tolerated (0.24); PolyPhen benign (0.003); catalogued as rs1158918046, COSV51008932; called by muse, varscan2
- TCF7L2 | c.1810G>T p.A604S (on ENST00000355995 / NM_001367943.1; = p.A581S on NM_030756.5) | Missense Mutation (SNP) | VAF 19/102 reads (19%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.132); catalogued as COSV53342163; called by muse, mutect2, varscan2
- TCP11L1 | c.1298G>T p.S433I | Missense Mutation (SNP) | VAF 18/126 reads (14%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.58); catalogued as rs745362450, COSV100178098; called by muse, mutect2, varscan2
- TEP1 | c.1961G>C p.R654T | Missense Mutation (SNP) | VAF 49/266 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.812); catalogued as COSV52994075; called by muse, mutect2, varscan2
- TEX15 | c.3056C>G p.T1019S (on ENST00000256246; = p.T1402S on NM_001350162.2) | Missense Mutation (SNP) | VAF 65/373 reads (17%) | SIFT tolerated (0.31); PolyPhen benign (0.013); catalogued as COSV56347696; called by muse, mutect2, varscan2
- THADA | c.3257T>A p.V1086E | Missense Mutation (SNP) | VAF 34/104 reads (33%) | SIFT tolerated (0.25); PolyPhen benign (0.067); catalogued as COSV57685560; called by muse, mutect2, varscan2
- THEMIS | c.1163A>T p.Q388L | Missense Mutation (SNP) | VAF 27/111 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.583); catalogued as COSV64071719; called by muse, mutect2, varscan2
- THOC2 | c.1978C>G p.L660V | Missense Mutation (SNP) | VAF 8/133 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.749); catalogued as COSV55547676; called by muse, mutect2
- THOP1 | c.65A>G p.N22S | Missense Mutation (SNP) | VAF 67/157 reads (43%) | SIFT deleterious (0.02); PolyPhen benign (0.244); catalogued as COSV57019021; called by muse, mutect2, varscan2
- TMEM39A | c.925-1G>C p.X309_splice | Splice Site (SNP) | VAF 48/226 reads (21%) | catalogued as COSV59900637; called by muse, mutect2
- TNN | c.1567G>A p.A523T | Missense Mutation (SNP) | VAF 17/137 reads (12%) | SIFT tolerated (0.1); PolyPhen benign (0.157); catalogued as COSV53428067; called by muse, mutect2, varscan2
- TNR | c.2756C>G p.T919S | Missense Mutation (SNP) | VAF 49/215 reads (23%) | SIFT tolerated (0.22); PolyPhen benign (0.287); catalogued as COSV54890535; called by muse, mutect2, varscan2
- TRIML2 | c.448G>A p.E150K | Missense Mutation (SNP) | VAF 17/88 reads (19%) | SIFT tolerated (0.38); PolyPhen possibly damaging (0.666); catalogued as rs781309682, COSV58716778; called by muse, mutect2, varscan2
- TRPC4 | c.911C>A p.P304H | Missense Mutation (SNP) | VAF 30/53 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV58992013, COSV59002906; called by muse, mutect2, varscan2
- TRRAP | c.4037A>G p.E1346G | Missense Mutation (SNP) | VAF 41/99 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.748); catalogued as COSV62846293; called by muse, mutect2, varscan2
- TTC21A | c.3380G>T p.R1127L | Missense Mutation (SNP) | VAF 31/65 reads (48%) | SIFT deleterious (0.04); PolyPhen benign (0.042); catalogued as COSV56187819; called by muse, mutect2, varscan2
- TTC22 | c.296A>G p.N99S | Missense Mutation (SNP) | VAF 13/32 reads (41%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.987); catalogued as COSV64881522; called by muse, mutect2
- TTC7A | c.1773G>T p.M591I | Missense Mutation (SNP) | VAF 51/202 reads (25%) | SIFT tolerated (0.1); PolyPhen benign (0.293); catalogued as COSV99766354; called by muse, mutect2, varscan2
- TTN | c.38284G>T p.V12762L (on ENST00000591111; = p.V5338L on NM_003319.4) | Missense Mutation (SNP) | VAF 30/259 reads (12%) | PolyPhen probably damaging (0.99); catalogued as COSV60117868; called by muse, mutect2, varscan2
- TTN | c.31412C>T p.S10471F (on ENST00000591111; = p.S9544F on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 18/49 reads (37%) | PolyPhen benign (0.323); catalogued as COSV60030702, COSV60117911; called by muse, mutect2, varscan2
- TTN | c.6671C>A p.S2224Y (on ENST00000591111; = p.S2178Y on NM_003319.4) | Missense Mutation (SNP) | VAF 47/135 reads (35%) | PolyPhen probably damaging (0.998); catalogued as COSV100613880, COSV60117925; called by muse, mutect2, varscan2
- UBR1 | c.4520C>T p.P1507L | Missense Mutation (SNP) | VAF 6/110 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.797); catalogued as COSV51931110; called by muse, mutect2
- UBTF | c.1813C>T p.Q605* | Nonsense Mutation (SNP) | VAF 25/106 reads (24%) | catalogued as COSV57186627; called by muse, mutect2, varscan2
- UNC13C | c.755G>T p.G252V | Missense Mutation (SNP) | VAF 31/127 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV52882907; called by muse, mutect2, varscan2
- UNC13C | c.1727G>T p.S576I | Missense Mutation (SNP) | VAF 14/71 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.601); catalogued as COSV52882944; called by muse, mutect2, varscan2
- UNC13C | c.2561C>A p.T854K | Missense Mutation (SNP) | VAF 30/88 reads (34%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.339); catalogued as rs375077921, COSV52882984; called by muse, mutect2, varscan2
- USP54 | c.1925G>C p.R642P | Missense Mutation (SNP) | VAF 69/259 reads (27%) | SIFT tolerated (0.11); PolyPhen benign (0.015); catalogued as COSV100161513, COSV60443612; called by muse, mutect2, varscan2
- USP9X | c.899A>G p.N300S | Missense Mutation (SNP) | VAF 95/104 reads (91%) | SIFT tolerated (0.33); PolyPhen benign (0.345); catalogued as COSV61070002; called by muse, mutect2, varscan2
- VTI1A | c.479T>A p.I160K | Missense Mutation (SNP) | VAF 9/47 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV67580992; called by muse, mutect2, varscan2
- WASHC4 | c.2090G>T p.R697L | Missense Mutation (SNP) | VAF 33/140 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.739); catalogued as COSV59888338, COSV59890135; called by muse, mutect2, varscan2
- WFDC11 | c.125G>A p.C42Y | Missense Mutation (SNP) | VAF 74/251 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60975881, COSV60975977; called by muse, mutect2, varscan2
- WFS1 | c.1576G>T p.G526C | Missense Mutation (SNP) | VAF 24/194 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99901220; called by muse, mutect2, varscan2
- WFS1 | c.1577G>T p.G526V | Missense Mutation (SNP) | VAF 25/193 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99901225; called by muse, mutect2, varscan2
- WIPF3 | c.1253A>T p.D418V | Missense Mutation (SNP) | VAF 12/58 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV54209554; called by muse, mutect2, varscan2
- WNK1 | c.1698G>C p.K566N | Missense Mutation (SNP) | VAF 80/420 reads (19%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.833); catalogued as rs766215765, COSV60035564; called by muse, mutect2, varscan2
- WNT10B | c.437G>T p.C146F | Missense Mutation (SNP) | VAF 25/83 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs944556493, COSV56405576; called by muse, mutect2, varscan2
- WNT7B | c.775A>T p.S259C | Missense Mutation (SNP) | VAF 54/170 reads (32%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.838); catalogued as COSV59750576; called by muse, varscan2
- WT1 | c.1304G>T p.G435V | Missense Mutation (SNP) | VAF 122/347 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.99); catalogued as COSV60066682, COSV60086086; called by muse, mutect2, varscan2
- XCL1 | c.182T>C p.I61T | Missense Mutation (SNP) | VAF 33/83 reads (40%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.505); catalogued as COSV63192269; called by muse, mutect2, varscan2
- XIRP2 | c.2215T>C p.W739R (on ENST00000628543; = p.W914R on NM_152381.6) | Missense Mutation (SNP) | VAF 27/103 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54706985; called by muse, mutect2, varscan2
- ZBBX | c.319C>A p.Q107K | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT tolerated (0.06); PolyPhen benign (0.075); catalogued as rs1387339659, COSV56788476; called by muse, mutect2, varscan2
- ZBTB20 | c.2208G>T p.M736I (on ENST00000474710 / NM_001164342.2; = p.M663I on NM_015642.6 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 45/122 reads (37%) | SIFT tolerated, low confidence (0.45); PolyPhen benign (0.333); catalogued as COSV61853235; called by muse, mutect2, varscan2
- ZC3H12C | c.2041C>T p.H681Y | Missense Mutation (SNP) | VAF 73/588 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.968); catalogued as COSV53709421; called by muse, mutect2, varscan2
- ZC3H18 | c.604G>T p.D202Y | Missense Mutation (SNP) | VAF 24/106 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV56325408; called by muse, varscan2
- ZC3HAV1L | c.744G>C p.K248N | Missense Mutation (SNP) | VAF 26/203 reads (13%) | SIFT tolerated (0.1); PolyPhen benign (0.006); catalogued as COSV51964552; called by muse, mutect2, varscan2
- ZEB1 | c.2528A>G p.Y843C | Missense Mutation (SNP) | VAF 64/122 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1459247481, COSV58046125; called by muse, mutect2, varscan2
- ZFHX4 | c.8564C>A p.P2855H | Missense Mutation (SNP) | VAF 26/84 reads (31%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.963); catalogued as COSV50996677; called by muse, mutect2, varscan2
- ZFYVE28 | c.910G>A p.A304T | Missense Mutation (SNP) | VAF 45/117 reads (38%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as rs1159241736, COSV52111439; called by muse, mutect2, varscan2
- ZFYVE9 | c.1018C>T p.L340F | Missense Mutation (SNP) | VAF 56/183 reads (31%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0); catalogued as rs1374454652, COSV55094876; called by muse, mutect2, varscan2
- ZGRF1 | c.6025G>A p.V2009I | Missense Mutation (SNP) | VAF 5/38 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.554); catalogued as COSV71393284; called by muse, mutect2, varscan2
- ZIC4 | c.812G>A p.C271Y | Missense Mutation (SNP) | VAF 24/80 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67172226; called by muse, varscan2
- ZIC4 | c.735C>A p.F245L | Missense Mutation (SNP) | VAF 27/69 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67172232, COSV67173973; called by muse, varscan2
- ZNF292 | c.5523A>T p.L1841F | Missense Mutation (SNP) | VAF 16/48 reads (33%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.896); catalogued as rs1007408934, COSV60540718; called by muse, mutect2, varscan2
- ZNF318 | c.3385T>C p.F1129L | Missense Mutation (SNP) | VAF 8/150 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as COSV58933359; called by muse, mutect2
- ZNF343 | c.1580G>T p.G527V | Missense Mutation (SNP) | VAF 49/148 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV53854219; called by muse, mutect2, varscan2
- ZNF569 | c.1791G>T p.M597I | Missense Mutation (SNP) | VAF 85/167 reads (51%) | SIFT tolerated (0.05); PolyPhen benign (0.003); catalogued as COSV57596096; called by muse, mutect2, varscan2
- ZNF644 | c.61G>T p.G21W | Missense Mutation (SNP) | VAF 36/184 reads (20%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.793); catalogued as COSV61348199; called by muse, mutect2, varscan2
- ZNF697 | c.1327G>A p.G443R | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1256431627, COSV70284014; called by muse, mutect2, varscan2
- ZNF80 | c.398A>G p.Y133C | Missense Mutation (SNP) | VAF 8/103 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.847); catalogued as rs143330045; called by muse, mutect2
- ZP4 | c.1112C>T p.P371L | Missense Mutation (SNP) | VAF 13/216 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV63912302; called by muse, mutect2
- ZSCAN20 | c.635C>T p.P212L | Missense Mutation (SNP) | VAF 19/78 reads (24%) | SIFT deleterious (0.04); PolyPhen benign (0.026); catalogued as COSV63683047; called by muse, mutect2, varscan2
- ZZZ3 | c.406C>T p.P136S | Missense Mutation (SNP) | VAF 91/267 reads (34%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.007); catalogued as rs770456689, COSV66233433; called by muse, mutect2, varscan2
- CEP170 | c.685G>A p.E229K | Missense Mutation (SNP) | VAF 4/11 reads (36%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.621); called by mutect2, varscan2
- CLSTN2 | c.2176del p.D726Mfs*17 | Frame Shift Del (DEL) | VAF 18/116 reads (16%) | called by mutect2, pindel, varscan2
- COL6A6 | c.1370dup p.F458Vfs*15 | Frame Shift Ins (INS) | VAF 26/156 reads (17%) | called by mutect2, pindel, varscan2
- FAM71A | c.1628del p.G543Afs*8 | Frame Shift Del (DEL) | VAF 68/195 reads (35%) | called by mutect2, pindel, varscan2
- FCGBP | c.9443A>G p.E3148G | Missense Mutation (SNP) | VAF 45/160 reads (28%) | SIFT tolerated (0.2); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- GNG2 | c.18del p.A7Pfs*3 | Frame Shift Del (DEL) | VAF 32/112 reads (29%) | called by mutect2, varscan2
- HELQ | c.146_162delinsCG p.E49_K54delinsA | In Frame Del (DEL) | VAF 30/236 reads (13%) | called by pindel, varscan2*
- ITGB2 | c.2161del p.A721Qfs*18 (on ENST00000302347; = p.A697Qfs*18 on NM_000211.5 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 20/40 reads (50%) | called by mutect2, varscan2
- KCNA6 | c.1123del p.E375Sfs*46 | Frame Shift Del (DEL) | VAF 14/52 reads (27%) | called by mutect2, varscan2
- KIAA1210 | c.1042C>T p.P348S | Missense Mutation (SNP) | VAF 36/532 reads (7%) | SIFT tolerated (1); PolyPhen benign (0.029); called by muse, mutect2
- KNG1 | c.734_751del p.S245_I250del | In Frame Del (DEL) | VAF 10/48 reads (21%) | called by mutect2, pindel
- LACRT | c.74_106del p.D25_A35del | In Frame Del (DEL) | VAF 48/381 reads (13%) | called by mutect2, pindel
- NBPF26 | c.2346G>T p.W782C (on ENST00000620612; = p.W520C on NM_001351372.1) | Missense Mutation (SNP) | VAF 66/181 reads (36%) | SIFT tolerated (0.19); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- NOTCH1 | c.5443dup p.D1815Gfs*19 | Frame Shift Ins (INS) | VAF 60/134 reads (45%) | called by mutect2, pindel, varscan2
- OPHN1 | c.2097del p.K700Rfs*7 | Frame Shift Del (DEL) | VAF 8/21 reads (38%) | called by mutect2, pindel, varscan2
- PCDHGC4 | c.1097G>T p.G366V | Missense Mutation (SNP) | VAF 7/116 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- PRAMEF18 | c.287+1G>C p.X96_splice | Splice Site (SNP) | VAF 22/721 reads (3%) | called by muse, mutect2
- REG1B | c.81_83del p.E28del | In Frame Del (DEL) | VAF 60/294 reads (20%) | called by mutect2, pindel, varscan2
- ZNF623 | c.891del p.K298Rfs*89 | Frame Shift Del (DEL) | VAF 29/148 reads (20%) | called by mutect2, pindel, varscan2
- ACE | c.312G>T p.L104= | Silent (SNP) | VAF 18/52 reads (35%) | catalogued as COSV52021726; called by muse, mutect2, varscan2
- ACSM1 | c.1515G>T p.P505= | Silent (SNP) | VAF 29/88 reads (33%) | catalogued as COSV54636084, COSV54636579; called by muse, mutect2, varscan2
- ADAMTS20 | c.1578G>A p.V526= | Silent (SNP) | VAF 5/22 reads (23%) | catalogued as COSV67133100; called by muse, mutect2, varscan2
- ADCY2 | c.843G>T p.L281= | Silent (SNP) | VAF 29/125 reads (23%) | catalogued as COSV57877139; called by muse, mutect2, varscan2
- ADCY2 | c.1782C>T p.A594= | Silent (SNP) | VAF 9/265 reads (3%) | catalogued as COSV57865864, COSV57877157; called by muse, mutect2
- ADGRF4 | c.1512C>T p.V504= | Silent (SNP) | VAF 24/503 reads (5%) | catalogued as COSV51953276; called by muse, mutect2
- AGAP3 | c.945C>T p.R315= (on ENST00000622464; = p.R351= on NM_031946.7 and 1 other RefSeq transcript) | Silent (SNP) | VAF 10/110 reads (9%) | catalogued as COSV58994902; called by muse, mutect2, varscan2
- AMIGO2 | c.810T>C p.R270= | Silent (SNP) | VAF 8/137 reads (6%) | catalogued as COSV56974484; called by muse, mutect2
- ANK3 | c.2847A>G p.L949= (on ENST00000280772 / NM_001320874.2; = p.L83= on NM_001149.3) | Silent (SNP) | VAF 10/74 reads (14%) | catalogued as COSV55062187; called by muse, mutect2, varscan2
- ANTXR1 | c.627A>G p.Q209= | Silent (SNP) | VAF 31/296 reads (10%) | catalogued as COSV58014870; called by muse, mutect2, varscan2
- ATG7 | c.903A>G p.A301= | Silent (SNP) | VAF 15/87 reads (17%) | catalogued as rs1559428672, COSV61613121; called by muse, mutect2, varscan2
- BPIFB3 | c.1416G>T p.L472= | Silent (SNP) | VAF 40/174 reads (23%) | catalogued as COSV64957458; called by muse, mutect2, varscan2
- C20orf194 | c.654G>A p.K218= | Silent (SNP) | VAF 6/98 reads (6%) | catalogued as COSV52697190; called by muse, mutect2
- C21orf62 | c.195C>T p.T65= | Silent (SNP) | VAF 12/148 reads (8%) | catalogued as rs200043583; called by muse, mutect2
- C2CD3 | c.1713G>A p.V571= | Silent (SNP) | VAF 6/60 reads (10%) | catalogued as COSV58092450; called by mutect2, varscan2
- CADPS2 | c.1089G>T p.L363= | Silent (SNP) | VAF 12/190 reads (6%) | catalogued as COSV100463403, COSV57367074; called by muse, mutect2
- CCDC178 | c.2445G>T p.V815= (on ENST00000383096 / NM_001105528.3; = p.V777= on NM_198995.3) | Silent (SNP) | VAF 23/85 reads (27%) | catalogued as COSV55777387; called by muse, mutect2, varscan2
- CD300C | c.291G>A p.L97= | Silent (SNP) | VAF 46/162 reads (28%) | catalogued as COSV58170647; called by muse, mutect2, varscan2
- CDC42BPB | c.3786C>G p.L1262= | Silent (SNP) | VAF 13/91 reads (14%) | catalogued as rs141924737, COSV63475359; called by muse, mutect2, varscan2
- CFAP161 | c.300G>A p.Q100= | Silent (SNP) | VAF 29/143 reads (20%) | catalogued as rs1203561656, COSV54429554; called by muse, mutect2, varscan2
- CHPF2 | c.375C>A p.A125= | Silent (SNP) | VAF 49/228 reads (21%) | catalogued as COSV50391801; called by muse, mutect2, varscan2
- CLMN | c.636G>C p.A212= | Silent (SNP) | VAF 36/304 reads (12%) | catalogued as COSV54183194; called by muse, varscan2
- CLSTN2 | c.2007C>T p.A669= | Silent (SNP) | VAF 38/136 reads (28%) | catalogued as COSV71721383; called by muse, mutect2, varscan2
- CMKLR1 | c.84G>A p.L28= (on ENST00000312143 / NM_001142344.2; = p.L26= on NM_004072.3) | Silent (SNP) | VAF 32/83 reads (39%) | catalogued as COSV56438923; called by muse, mutect2, varscan2
- CNOT1 | c.3987C>G p.L1329= | Silent (SNP) | VAF 25/164 reads (15%) | catalogued as COSV55317832; called by muse, mutect2, varscan2
- CNTRL | c.4581A>C p.A1527= | Silent (SNP) | VAF 47/117 reads (40%) | catalogued as COSV53048235; called by muse, mutect2, varscan2
- CRACD | c.1605G>T p.R535= | Silent (SNP) | VAF 21/42 reads (50%) | catalogued as COSV51723006; called by muse, mutect2, varscan2
- CSMD3 | c.3450T>C p.Y1150= (on ENST00000297405 / NM_001363185.1; = p.Y1046= on NM_052900.3) | Silent (SNP) | VAF 30/127 reads (24%) | catalogued as rs1344747257, COSV52204699; called by muse, mutect2, varscan2
- DCSTAMP | c.883C>T p.L295= | Silent (SNP) | VAF 63/336 reads (19%) | catalogued as rs1291584525, COSV52578147; called by muse, mutect2, varscan2
- DDX60L | c.1872T>A p.V624= | Silent (SNP) | VAF 8/22 reads (36%) | catalogued as COSV52714933; called by muse, mutect2, varscan2
- DKK2 | c.483A>T p.G161= | Silent (SNP) | VAF 48/208 reads (23%) | catalogued as COSV53398617; called by muse, mutect2, varscan2
- DPAGT1 | c.525G>T p.L175= | Silent (SNP) | VAF 65/277 reads (23%) | catalogued as rs773623306, COSV100830652, COSV62614558; called by muse, mutect2, varscan2
- EDN2 | c.264G>A p.R88= | Silent (SNP) | VAF 16/55 reads (29%) | catalogued as COSV65423475; called by muse, mutect2, varscan2
- EFL1 | c.291G>T p.V97= | Silent (SNP) | VAF 15/73 reads (21%) | catalogued as COSV51606435; called by muse, mutect2, varscan2
- EML4 | c.1716A>G p.R572= | Silent (SNP) | VAF 30/205 reads (15%) | catalogued as COSV59299545; called by muse, mutect2, varscan2
- FAF2 | c.444G>A p.G148= | Silent (SNP) | VAF 15/90 reads (17%) | catalogued as COSV56131379; called by muse, varscan2
- FAP | c.1299T>A p.P433= | Silent (SNP) | VAF 22/114 reads (19%) | catalogued as COSV51862727; called by muse, mutect2, varscan2
- FAR2 | c.1434C>T p.A478= | Silent (SNP) | VAF 42/233 reads (18%) | catalogued as COSV51726374; called by muse, mutect2, varscan2
- FKBP3 | c.18A>T p.P6= | Silent (SNP) | VAF 28/68 reads (41%) | catalogued as COSV53532762; called by muse, mutect2, varscan2
- FOXA3 | c.867A>T p.P289= | Silent (SNP) | VAF 43/69 reads (62%) | catalogued as COSV56216359; called by muse, mutect2, varscan2
- FRMPD1 | c.522T>C p.N174= | Silent (SNP) | VAF 89/132 reads (67%) | catalogued as COSV66700686; called by muse, mutect2, varscan2
- FRY | c.3969A>T p.S1323= | Silent (SNP) | VAF 94/166 reads (57%) | catalogued as COSV66571822; called by muse, mutect2, varscan2
- FST | c.399G>A p.G133= | Silent (SNP) | VAF 26/92 reads (28%) | catalogued as COSV56815947; called by muse, mutect2, varscan2
- GLRA2 | c.789C>T p.I263= | Silent (SNP) | VAF 22/124 reads (18%) | catalogued as COSV54342163; called by muse, mutect2, varscan2
- GNPDA2 | c.486A>G p.L162= | Silent (SNP) | VAF 43/145 reads (30%) | catalogued as rs770413825, COSV54947010; called by muse, mutect2, varscan2
- GPAT2 | c.1797G>T p.P599= | Silent (SNP) | VAF 4/32 reads (13%) | catalogued as rs531152623, COSV100853266; called by mutect2, varscan2
- GPKOW | c.846G>A p.V282= | Silent (SNP) | VAF 185/962 reads (19%) | catalogued as COSV50243105; called by muse, varscan2
- H2AC14 | c.66C>A p.A22= | Silent (SNP) | VAF 49/115 reads (43%) | catalogued as COSV60797836; called by muse, mutect2, varscan2
- HEATR5B | c.478C>T p.L160= | Silent (SNP) | VAF 53/239 reads (22%) | catalogued as COSV51853929; called by muse, mutect2, varscan2
- HEATR6 | c.1884G>A p.K628= | Silent (SNP) | VAF 44/304 reads (14%) | catalogued as COSV51746279; called by muse, mutect2, varscan2
- HMGCS1 | c.684A>G p.A228= | Silent (SNP) | VAF 68/246 reads (28%) | catalogued as COSV57290421; called by muse, mutect2, varscan2
- HNRNPU | c.1932G>A p.G644= (on ENST00000283179; = p.G706= on NM_004501.3) | Silent (SNP) | VAF 15/123 reads (12%) | catalogued as COSV51691702; called by muse, mutect2, varscan2
- IL21R | c.726C>G p.L242= | Silent (SNP) | VAF 31/112 reads (28%) | catalogued as COSV61970890; called by muse, mutect2, varscan2
- ILDR1 | c.1092G>T p.L364= (on ENST00000344209 / NM_001199799.2; = p.L320= on NM_175924.4) | Silent (SNP) | VAF 19/108 reads (18%) | catalogued as COSV56550697; called by muse, mutect2, varscan2
- IMPG1 | c.798C>T p.S266= | Silent (SNP) | VAF 29/196 reads (15%) | catalogued as COSV64058725; called by muse, mutect2, varscan2
- KCNA2 | c.813G>A p.G271= | Silent (SNP) | VAF 47/236 reads (20%) | catalogued as rs1557732360, COSV60370272; called by muse, mutect2, varscan2
- KCNC2 | c.1152G>T p.L384= | Silent (SNP) | VAF 18/92 reads (20%) | catalogued as COSV54370603; called by muse, mutect2, varscan2
- KCNMA1 | c.2658C>G p.L886= (on ENST00000286628 / NM_001161352.2; = p.L828= on NM_002247.4) | Silent (SNP) | VAF 11/228 reads (5%) | catalogued as COSV54254367; called by muse, mutect2
- LCE3A | c.147G>C p.L49= | Silent (SNP) | VAF 16/164 reads (10%) | catalogued as COSV59550542, COSV59550704; called by muse, mutect2, varscan2
- LIG1 | c.2547C>T p.L849= | Silent (SNP) | VAF 9/32 reads (28%) | catalogued as COSV54392647; called by muse, mutect2, varscan2
- LPAR4 | c.588C>A p.V196= | Silent (SNP) | VAF 9/39 reads (23%) | catalogued as COSV101425136, COSV70912773, COSV70913244; called by muse, mutect2, varscan2
- MED1 | c.3177C>G p.P1059= | Silent (SNP) | VAF 322/518 reads (62%) | catalogued as COSV56125534; called by muse, varscan2
- MEX3C | c.903C>T p.S301= | Silent (SNP) | VAF 28/68 reads (41%) | catalogued as COSV68530004; called by muse, mutect2, varscan2
- MYH4 | c.309G>A p.L103= | Silent (SNP) | VAF 52/130 reads (40%) | catalogued as COSV55119612; called by muse, mutect2, varscan2
- NCDN | c.1734G>A p.R578= | Silent (SNP) | VAF 24/88 reads (27%) | catalogued as rs761372029, COSV61935954; called by muse, mutect2, varscan2
- NLGN4Y | c.1167T>A p.G389= | Silent (SNP) | VAF 10/28 reads (36%) | catalogued as COSV100196741; called by mutect2, varscan2
- NRXN3 | c.2991G>T p.L997= (on ENST00000335750 / NM_001330195.2; = p.L624= on NM_004796.6) | Silent (SNP) | VAF 53/146 reads (36%) | catalogued as COSV59730524, COSV59759396; called by muse, mutect2, varscan2
- ODF3B | c.615G>T p.L205= | Silent (SNP) | VAF 10/39 reads (26%) | catalogued as COSV52688173; called by muse, mutect2, varscan2
- OR4C3 | c.153C>T p.P51= | Silent (SNP) | VAF 12/145 reads (8%) | catalogued as rs1387886892, COSV60586794, COSV60590744; called by muse, mutect2
- OR51E1 | c.357G>T p.L119= | Silent (SNP) | VAF 23/124 reads (19%) | catalogued as COSV67810181; called by muse, mutect2, varscan2
- OR6N1 | c.858C>T p.N286= | Silent (SNP) | VAF 94/378 reads (25%) | catalogued as COSV58648940, COSV58649658; called by muse, mutect2, varscan2
- OR7A17 | c.297C>G p.T99= | Silent (SNP) | VAF 49/102 reads (48%) | catalogued as COSV59414179, COSV59414412; called by muse, mutect2, varscan2
- OTOA | c.2094C>T p.I698= (on ENST00000286149; = p.I684= on NM_144672.4) | Silent (SNP) | VAF 63/212 reads (30%) | catalogued as COSV53756285; called by muse, mutect2, varscan2
- OTUD7A | c.249T>C p.G83= | Silent (SNP) | VAF 22/138 reads (16%) | catalogued as COSV61039611; called by muse, varscan2
- PAPSS2 | c.801C>G p.P267= | Silent (SNP) | VAF 8/60 reads (13%) | catalogued as rs966311239, COSV63263617; called by muse, mutect2, varscan2
- PDILT | c.33G>A p.V11= | Silent (SNP) | VAF 44/249 reads (18%) | catalogued as COSV56702482; called by muse, mutect2, varscan2
- PIGR | c.264G>T p.P88= | Silent (SNP) | VAF 15/115 reads (13%) | catalogued as COSV62904250; called by muse, mutect2, varscan2
- PIGT | c.450A>T p.T150= | Silent (SNP) | VAF 68/261 reads (26%) | catalogued as COSV54126751; called by muse, mutect2, varscan2
- PIK3CG | c.2802C>T p.G934= | Silent (SNP) | VAF 118/328 reads (36%) | catalogued as COSV63249274; called by muse, mutect2, varscan2
- PIK3R5 | c.2433C>T p.N811= | Silent (SNP) | VAF 49/163 reads (30%) | catalogued as COSV52654824; called by muse, mutect2, varscan2
- PLA2G4F | c.2454C>T p.L818= | Silent (SNP) | VAF 11/87 reads (13%) | catalogued as rs778625779, COSV51827355; called by muse, mutect2, varscan2
- POU2F3 | c.588G>A p.K196= | Silent (SNP) | VAF 30/285 reads (11%) | catalogued as COSV52794617; called by muse, mutect2, varscan2
- POU3F4 | c.243G>T p.V81= | Silent (SNP) | VAF 7/10 reads (70%) | catalogued as COSV64539330; called by mutect2, varscan2
- PRDM9 | c.645C>T p.S215= | Silent (SNP) | VAF 12/124 reads (10%) | catalogued as COSV57007565; called by muse, mutect2
- PRMT9 | c.2475A>G p.G825= | Silent (SNP) | VAF 39/209 reads (19%) | catalogued as COSV56853872; called by muse, mutect2, varscan2
- PROSER2 | c.813G>T p.L271= | Silent (SNP) | VAF 9/12 reads (75%) | catalogued as COSV53206224; called by muse, mutect2, varscan2
- RGS4 | c.216G>C p.G72= | Silent (SNP) | VAF 39/192 reads (20%) | catalogued as COSV63357546; called by muse, mutect2, varscan2
- RHBDD1 | c.513G>A p.P171= | Silent (SNP) | VAF 57/337 reads (17%) | catalogued as rs749652821, COSV58125794, COSV58128471; called by muse, mutect2, varscan2
- RPS6KC1 | c.3177G>C p.V1059= | Silent (SNP) | VAF 11/152 reads (7%) | catalogued as COSV65300013, COSV65301607; called by muse, mutect2
- RXFP3 | c.592C>A p.R198= | Silent (SNP) | VAF 48/128 reads (38%) | catalogued as COSV57504472, COSV57506141; called by muse, mutect2, varscan2
- RYR2 | c.7020G>A p.G2340= | Silent (SNP) | VAF 22/69 reads (32%) | catalogued as rs767884614, COSV63687686; called by muse, mutect2, varscan2
- RYR3 | c.5556G>A p.L1852= | Silent (SNP) | VAF 6/43 reads (14%) | catalogued as rs1432536910, COSV66778682; called by muse, mutect2, varscan2
- SALL3 | c.1752A>G p.P584= | Silent (SNP) | VAF 11/15 reads (73%) | catalogued as rs1191349183, COSV73306127; called by muse, mutect2, varscan2
- SDK2 | c.3210C>A p.R1070= | Silent (SNP) | VAF 12/96 reads (13%) | catalogued as COSV66187825; called by muse, mutect2, varscan2
- SFMBT2 | c.651C>T p.R217= | Silent (SNP) | VAF 14/203 reads (7%) | catalogued as COSV62810908; called by muse, mutect2
- SH3BP4 | c.1851C>T p.I617= | Silent (SNP) | VAF 9/113 reads (8%) | catalogued as rs967791605, COSV60644232, COSV60646175; called by muse, mutect2
- SLC35F4 | c.1368C>A p.R456= (on ENST00000339762 / NM_001352015.2; = p.R420= on NM_001206920.1 and 1 other RefSeq transcript) | Silent (SNP) | VAF 6/27 reads (22%) | catalogued as COSV60265217; called by muse, mutect2, varscan2
- SLC45A3 | c.927G>C p.P309= | Silent (SNP) | VAF 31/128 reads (24%) | catalogued as COSV65654850, COSV65655046; called by muse, mutect2, varscan2
- SLC6A1 | c.360T>A p.P120= | Silent (SNP) | VAF 57/323 reads (18%) | catalogued as COSV55115930; called by muse, mutect2, varscan2
- SPATA21 | c.1068G>A p.R356= | Silent (SNP) | VAF 153/511 reads (30%) | catalogued as COSV59187335; called by muse, mutect2, varscan2
- SPATA31D1 | c.2128C>T p.L710= | Silent (SNP) | VAF 39/88 reads (44%) | catalogued as rs756102985, COSV61196781; called by muse, mutect2, varscan2
- SPTLC1 | c.1383G>C p.A461= | Silent (SNP) | VAF 11/151 reads (7%) | catalogued as COSV52764595; called by muse, mutect2
- SSTR4 | c.132G>T p.A44= | Silent (SNP) | VAF 19/64 reads (30%) | catalogued as COSV54798551; called by muse, mutect2, varscan2
- ST3GAL1 | c.408G>T p.S136= | Silent (SNP) | VAF 39/165 reads (24%) | catalogued as COSV60613654; called by muse, mutect2, varscan2
- SYAP1 | c.645C>T p.L215= | Silent (SNP) | VAF 49/92 reads (53%) | catalogued as COSV66468181; called by muse, mutect2, varscan2
- TAFA5 | c.154C>A p.R52= (on ENST00000402357 / NM_001082967.3; = p.R45= on NM_015381.7) | Silent (SNP) | VAF 8/68 reads (12%) | catalogued as rs944569676, COSV100385932; called by muse, mutect2
- TENM1 | c.3501C>G p.V1167= | Silent (SNP) | VAF 40/54 reads (74%) | catalogued as COSV64433968; called by muse, mutect2, varscan2
- TIMD4 | c.123G>C p.L41= | Silent (SNP) | VAF 44/97 reads (45%) | catalogued as COSV50856082, COSV50858165; called by muse, mutect2, varscan2
- TMEM106C | c.132C>T p.T44= | Silent (SNP) | VAF 19/62 reads (31%) | catalogued as rs774457348, COSV56742892; called by muse, mutect2, varscan2
- TOP2A | c.4476G>A p.K1492= | Silent (SNP) | VAF 4/48 reads (8%) | catalogued as rs1200513076, COSV101352301, COSV68503077; called by muse, mutect2
- TROAP | c.426G>T p.G142= | Silent (SNP) | VAF 21/125 reads (17%) | catalogued as COSV57744698; called by muse, mutect2, varscan2
- TRPV6 | c.1977C>T p.C659= | Silent (SNP) | VAF 7/74 reads (9%) | catalogued as rs373768674; called by muse, mutect2, varscan2
- TTLL2 | c.1449A>T p.A483= | Silent (SNP) | VAF 31/155 reads (20%) | catalogued as COSV53444325; called by muse, mutect2, varscan2
- TUBG2 | c.1098C>T p.Y366= | Silent (SNP) | VAF 29/300 reads (10%) | catalogued as rs535157594, COSV52218071; called by muse, mutect2, varscan2
- WDR7 | c.2959T>C p.L987= | Silent (SNP) | VAF 98/176 reads (56%) | catalogued as COSV54354919; called by mutect2, varscan2
- ZBTB40 | c.1899C>A p.A633= | Silent (SNP) | VAF 44/302 reads (15%) | catalogued as COSV65145565; called by muse, mutect2, varscan2
- BTN2A3P | n.1762C>A | RNA (SNP) | VAF 96/291 reads (33%) | called by muse, mutect2, varscan2
- DLGAP1 | c.958-31007G>A | Intron (SNP) | VAF 11/88 reads (13%) | catalogued as COSV59789065; called by muse, mutect2, varscan2
- DPP6 | c.627+20975T>G | Intron (SNP) | VAF 92/269 reads (34%) | catalogued as COSV100125113; called by muse, varscan2
- DPP6 | c.627+21037G>T | Intron (SNP) | VAF 144/332 reads (43%) | catalogued as COSV100125114; called by muse, varscan2
- HK1 | chr10:69315960 C>T | 5'Flank (SNP) | VAF 34/228 reads (15%) | catalogued as COSV100066432; called by muse, mutect2, varscan2
- IGF2BP2 | c.240-15094A>G | Intron (SNP) | VAF 14/83 reads (17%) | catalogued as COSV56211636; called by muse, mutect2, varscan2
- MAGEC3 | c.1124-193G>T | Intron (SNP) | VAF 147/206 reads (71%) | catalogued as COSV100025312; called by muse, mutect2, varscan2
- MAGED1 | c.46-315G>T | Intron (SNP) | VAF 20/55 reads (36%) | catalogued as COSV100431536, COSV58514333; called by muse, mutect2, varscan2
- MARCHF1 | c.-322-85936A>T | Intron (SNP) | VAF 55/291 reads (19%) | catalogued as COSV72278227; called by muse, mutect2, varscan2
- MASP1 | c.1303+5220C>G | Intron (SNP) | VAF 53/139 reads (38%) | catalogued as COSV99962238; called by muse, mutect2, varscan2
- MIR656 | n.38T>A | RNA (SNP) | VAF 23/109 reads (21%) | called by muse, mutect2, varscan2
- RN7SL484P | chr15:99792343 G>A | 3'Flank (SNP) | VAF 20/83 reads (24%) | called by muse, mutect2, varscan2
- RREB1 | c.3809-5923G>C | Intron (SNP) | VAF 64/216 reads (30%) | catalogued as COSV100619313; called by muse, mutect2, varscan2
- RRM2 | n.533G>A | RNA (SNP) | VAF 62/173 reads (36%) | called by muse, mutect2, varscan2
- SV2C | c.581-21050G>T | Intron (SNP) | VAF 156/333 reads (47%) | called by muse, mutect2, varscan2
